Somatic mutation profile of cancer-model specimen HCM-BROD-0561-C43-85M (Adherent Cell Line, passage 9; aliquot HCM-BROD-0561-C43-85M-01D-A79L-36), derived from the metastatic tumor of HCMI case HCM-BROD-0561-C43, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Vital status: Alive; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; AJCC pathologic stage: Stage IV; Age at diagnosis: 63.4 years (23,161 days).
Specimen HCM-BROD-0561-C43-85M: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: Adherent Cell Line; Preservation method: Frozen; Passage count: 9.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 0ca17649-d1e2-4523-9741-f044201faa1c.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-BROD-0561-C43-10A (Blood Derived Normal), aliquot HCM-BROD-0561-C43-10A-01D-A79L-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/f92e79a6-809c-4178-8a1d-cdae71649a22

The open-access MAF lists 716 somatic variants for this specimen: 484 protein-altering or splice-affecting, 209 silent, 23 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 434, Silent 209, Nonsense Mutation 34, Intron 13, Splice Region 7, Frame Shift Del 4, 3'UTR 3, 5'Flank 3, Splice Site 2, 5'UTR 2, In Frame Ins 2, Translation Start Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NRAS | c.183A>T p.Q61H | Missense Mutation (SNP) | VAF 255/433 reads (59%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.316); catalogued as rs121913255, COSV54736320, COSV54736991, COSV54744813; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- TP53 | c.902del p.P301Qfs*44 | Frame Shift Del (DEL) | VAF 238/244 reads (98%) | catalogued as rs876660726, COSV53267099, COSV53486315; ClinVar: pathogenic; called by mutect2, varscan2
- AADACL3 | c.1186A>T p.I396F | Missense Mutation (SNP) | VAF 233/444 reads (52%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs1264397376; called by muse, mutect2, varscan2
- ABCD3 | c.1273C>T p.P425S | Missense Mutation (SNP) | VAF 213/385 reads (55%) | SIFT tolerated (0.53); PolyPhen benign (0.001); catalogued as rs1202340033, COSV64644738; called by muse, mutect2, varscan2
- ABCG2 | c.475G>A p.E159K | Missense Mutation (SNP) | VAF 199/336 reads (59%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.46); catalogued as rs769012528, COSV99418745, COSV99419844; called by muse, mutect2, varscan2
- ABHD15 | c.1022C>T p.P341L | Missense Mutation (SNP) | VAF 330/490 reads (67%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs145964335; called by muse, mutect2, varscan2
- ABHD15 | c.1021C>T p.P341S | Missense Mutation (SNP) | VAF 328/488 reads (67%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1265822616; called by muse, mutect2, varscan2
- AC100868.1 | c.2039C>T p.P680L | Missense Mutation (SNP) | VAF 136/642 reads (21%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0.03); catalogued as rs761441732, COSV51845748; called by muse, mutect2, varscan2
- ACKR3 | c.863G>A p.R288Q | Missense Mutation (SNP) | VAF 188/609 reads (31%) | SIFT tolerated (0.68); PolyPhen benign (0); catalogued as rs753186392; called by muse, mutect2, varscan2
- ACTN2 | c.971G>A p.R324Q | Missense Mutation (SNP) | VAF 233/460 reads (51%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.987); catalogued as rs1240148760; called by muse, varscan2
- ADAMTSL4 | c.808G>A p.G270R | Missense Mutation (SNP) | VAF 266/627 reads (42%) | SIFT tolerated (0.22); PolyPhen benign (0.007); catalogued as COSV54996195; called by muse, mutect2, varscan2
- ADCY1 | c.1315C>T p.H439Y | Missense Mutation (SNP) | VAF 108/308 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52040303; called by muse, mutect2, varscan2
- ADGRB2 | c.4678C>T p.R1560* (on ENST00000373658 / NM_001364857.2; = p.R1559* on NM_001294335.2) | Nonsense Mutation (SNP) | VAF 244/551 reads (44%) | catalogued as rs976961418; called by muse, varscan2
- ADGRG6 | c.3479C>T p.S1160F | Missense Mutation (SNP) | VAF 191/191 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99749058; called by muse, mutect2, varscan2
- AHNAK | c.15782C>T p.S5261F | Missense Mutation (SNP) | VAF 299/448 reads (67%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs771792360; called by muse, mutect2, varscan2
- ALMS1 | c.7352C>T p.S2451L | Missense Mutation (SNP) | VAF 176/286 reads (62%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.526); catalogued as COSV52502907; called by muse, varscan2
- ALS2 | c.2158C>T p.L720F | Missense Mutation (SNP) | VAF 151/209 reads (72%) | SIFT deleterious (0); PolyPhen probably damaging (0.919); catalogued as COSV51885616; called by muse, mutect2, varscan2
- AMPD3 | c.724G>A p.E242K (on ENST00000396553 / NM_001025389.2; = p.E251K on NM_000480.3) | Missense Mutation (SNP) | VAF 337/462 reads (73%) | SIFT tolerated (0.45); PolyPhen benign (0.001); catalogued as rs751459310; called by muse, mutect2, varscan2
- AMPD3 | c.1255C>T p.R419W (on ENST00000396553 / NM_001025389.2; = p.R428W on NM_000480.3) | Missense Mutation (SNP) | VAF 75/247 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as rs374394284; called by muse, mutect2, varscan2
- ANKFN1 | c.3457G>A p.G1153S (on ENST00000653862; = p.G1006S on NM_001365758.1 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 276/394 reads (70%) | SIFT tolerated, low confidence (0.53); PolyPhen benign (0.021); catalogued as rs767680949; called by muse, mutect2, varscan2
- ANKRD18A | c.1888G>A p.D630N | Missense Mutation (SNP) | VAF 41/121 reads (34%) | SIFT deleterious (0.02); PolyPhen benign (0.018); catalogued as rs1445234878; called by muse, mutect2, varscan2
- ANTXR1 | c.242C>T p.S81F | Missense Mutation (SNP) | VAF 193/303 reads (64%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58021757; called by muse, mutect2, varscan2
- APOH | c.403C>T p.P135S | Missense Mutation (SNP) | VAF 119/374 reads (32%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs1567740983, COSV52773316; called by muse, mutect2, varscan2
- ARAP1 | c.953C>T p.P318L (on ENST00000393609 / NM_001040118.2; = p.P73L on NM_015242.4) | Missense Mutation (SNP) | VAF 394/602 reads (65%) | SIFT tolerated (0.67); PolyPhen benign (0); catalogued as rs746589096; called by muse, mutect2, varscan2
- ARHGAP21 | c.2945C>T p.P982L | Missense Mutation (SNP) | VAF 156/171 reads (91%) | SIFT tolerated (0.52); PolyPhen benign (0.079); catalogued as rs200969279, COSV100255604; called by muse, mutect2, varscan2
- ASNSD1 | c.1630C>T p.H544Y | Missense Mutation (SNP) | VAF 193/283 reads (68%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53624049; called by muse, mutect2, varscan2
- ASXL3 | c.1760G>A p.G587E | Missense Mutation (SNP) | VAF 325/589 reads (55%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.026); catalogued as rs770935265, COSV52472441; called by muse, mutect2, varscan2
- AXL | c.107C>T p.P36L | Missense Mutation (SNP) | VAF 276/289 reads (96%) | SIFT tolerated (0.06); PolyPhen probably damaging (1); catalogued as rs536724919, COSV56567831; called by muse, mutect2, varscan2
- BFAR | c.293C>T p.A98V | Missense Mutation (SNP) | VAF 222/231 reads (96%) | SIFT tolerated (0.37); PolyPhen benign (0.01); catalogued as rs1297792907, COSV55493943; called by muse, mutect2, varscan2
- BMP5 | c.869G>A p.G290E | Missense Mutation (SNP) | VAF 99/359 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.838); catalogued as COSV63701018; called by muse, mutect2
- BRDT | c.1036A>C p.M346L | Missense Mutation (SNP) | VAF 176/322 reads (55%) | SIFT tolerated (0.15); PolyPhen benign (0.006); catalogued as COSV62865659, COSV62866039; called by muse, mutect2, varscan2
- C19orf18 | c.319G>A p.V107I | Missense Mutation (SNP) | VAF 185/197 reads (94%) | SIFT tolerated (1); PolyPhen benign (0.009); catalogued as rs780592836, COSV100071660; called by muse, mutect2, varscan2
- C3orf33 | c.245G>A p.R82Q (on ENST00000340171 / NM_001308229.2; = p.R39Q on NM_173657.2) | Missense Mutation (SNP) | VAF 131/131 reads (100%) | SIFT tolerated (0.1); PolyPhen benign (0.267); catalogued as rs759430996; called by muse, mutect2, varscan2
- CACNA1C | c.3140G>A p.G1047E | Missense Mutation (SNP) | VAF 155/276 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59702154; called by muse, mutect2, varscan2
- CADM2 | c.241C>T p.R81C (on ENST00000407528 / NM_001167674.2; = p.R83C on NM_153184.4) | Missense Mutation (SNP) | VAF 209/432 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as rs139991481, COSV67406856; called by muse, mutect2, varscan2
- CALCRL | c.1369G>A p.E457K | Missense Mutation (SNP) | VAF 70/226 reads (31%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.125); catalogued as COSV101131038, COSV66475467; called by muse, mutect2, varscan2
- CCDC146 | c.815C>T p.S272F | Missense Mutation (SNP) | VAF 60/209 reads (29%) | SIFT deleterious (0.03); PolyPhen benign (0.223); catalogued as COSV53549163; called by muse, mutect2, varscan2
- CCRL2 | c.979G>A p.G327R | Missense Mutation (SNP) | VAF 244/503 reads (49%) | SIFT tolerated (0.48); PolyPhen benign (0); catalogued as rs755483032, COSV99050934; called by muse, mutect2, varscan2
- CCSER1 | c.190C>T p.R64C | Missense Mutation (SNP) | VAF 123/316 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs760274993, COSV100395785; called by muse, mutect2, varscan2
- CDH17 | c.979C>T p.H327Y | Missense Mutation (SNP) | VAF 125/812 reads (15%) | SIFT tolerated (0.28); PolyPhen benign (0.003); catalogued as COSV50334035; called by muse, mutect2
- CELSR3 | c.2149G>A p.E717K | Missense Mutation (SNP) | VAF 323/641 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV50850368; called by muse, mutect2, varscan2
- CENPX | c.36+1G>A p.X12_splice | Splice Site (SNP) | VAF 317/1097 reads (29%) | catalogued as COSV100141973; called by muse, mutect2, varscan2
- CENPX | c.36G>A p.K12= | Splice Region (SNP) | VAF 322/1109 reads (29%) | catalogued as rs1568011056, COSV60713021; called by muse, mutect2, varscan2
- CFAP61 | c.2419C>T p.P807S | Missense Mutation (SNP) | VAF 228/380 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs866241136; called by muse, mutect2, varscan2
- CHGB | c.1316G>A p.R439K | Missense Mutation (SNP) | VAF 114/348 reads (33%) | SIFT tolerated (0.21); PolyPhen benign (0.067); catalogued as rs771393741, COSV66759682, COSV66761431; called by muse, mutect2, varscan2
- CHST13 | c.470C>T p.P157L | Missense Mutation (SNP) | VAF 338/338 reads (100%) | SIFT tolerated (0.29); PolyPhen possibly damaging (0.688); catalogued as rs1161509789; called by muse, mutect2, varscan2
- CLEC18C | c.364G>A p.E122K | Missense Mutation (SNP) | VAF 322/1346 reads (24%) | SIFT tolerated (0.36); PolyPhen benign (0.003); catalogued as rs1267437901, COSV100032225; called by muse, mutect2
- CMYA5 | c.11542G>A p.G3848R | Missense Mutation (SNP) | VAF 186/372 reads (50%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs888397347; called by muse, mutect2, varscan2
- COL3A1 | c.2674C>T p.P892S | Missense Mutation (SNP) | VAF 76/322 reads (24%) | SIFT tolerated (0.07); PolyPhen benign (0.054); catalogued as COSV58581291; called by muse, mutect2, varscan2
- COL4A1 | c.1421G>A p.G474E | Missense Mutation (SNP) | VAF 240/499 reads (48%) | SIFT deleterious (0.04); PolyPhen benign (0.039); catalogued as COSV101011079; called by muse, mutect2, varscan2
- CPPED1 | c.316G>A p.E106K | Missense Mutation (SNP) | VAF 277/303 reads (91%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs1175173911; called by muse, mutect2, varscan2
- CR1L | c.746C>T p.S249F | Missense Mutation (SNP) | VAF 269/525 reads (51%) | SIFT tolerated (0.19); PolyPhen benign (0.082); catalogued as COSV54324849; called by muse, mutect2, varscan2
- CRY2 | c.1192C>T p.R398W | Missense Mutation (SNP) | VAF 82/277 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.926); catalogued as rs199709255, COSV69888765; called by muse, mutect2, varscan2
- CRYBG2 | c.4559C>T p.S1520F | Missense Mutation (SNP) | VAF 177/335 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1424264394; called by muse, mutect2, varscan2
- CUX1 | c.1787G>A p.W596* | Nonsense Mutation (SNP) | VAF 269/434 reads (62%) | catalogued as rs1554518634; called by muse, mutect2, varscan2
- CWF19L2 | c.950G>A p.R317K | Missense Mutation (SNP) | VAF 82/297 reads (28%) | SIFT tolerated (0.44); PolyPhen benign (0.005); catalogued as rs776508638; called by muse, mutect2, varscan2
- CYLC1 | c.1711G>A p.E571K | Missense Mutation (SNP) | VAF 233/233 reads (100%) | SIFT tolerated (0.63); PolyPhen benign (0.17); catalogued as COSV100254841; called by muse, mutect2, varscan2
- CYP19A1 | c.1370G>A p.R457Q | Missense Mutation (SNP) | VAF 103/307 reads (34%) | SIFT tolerated (0.29); PolyPhen benign (0.044); catalogued as rs770120065, COSV53057383; called by muse, mutect2, varscan2
- CYP2C18 | c.1060G>A p.E354K | Missense Mutation (SNP) | VAF 467/467 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs142667327, COSV53674528; called by muse, mutect2, varscan2
- CYP4F2 | c.1309C>T p.P437S | Missense Mutation (SNP) | VAF 12/291 reads (4%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.702); catalogued as rs1418098189, COSV55617077; called by muse, mutect2
- CYP4X1 | c.631C>T p.P211S | Missense Mutation (SNP) | VAF 143/304 reads (47%) | SIFT tolerated (1); PolyPhen benign (0.034); catalogued as COSV64150212; called by muse, mutect2, varscan2
- DDX4 | c.1925C>T p.S642F | Missense Mutation (SNP) | VAF 164/381 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV61756511; called by muse, mutect2, varscan2
- DHDH | c.874G>A p.V292I | Missense Mutation (SNP) | VAF 245/256 reads (96%) | SIFT deleterious (0.03); PolyPhen benign (0.035); catalogued as rs370625899; called by muse, mutect2, varscan2
- DNAH3 | c.2068C>T p.Q690* | Nonsense Mutation (SNP) | VAF 10/250 reads (4%) | catalogued as rs1567809414, COSV54521739; called by muse, mutect2
- DNAH6 | c.2872C>T p.P958S | Missense Mutation (SNP) | VAF 138/220 reads (63%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.967); catalogued as rs963087684; called by muse, mutect2, varscan2
- DNASE1L3 | c.370G>A p.D124N | Missense Mutation (SNP) | VAF 182/381 reads (48%) | SIFT tolerated (0.16); PolyPhen benign (0.001); catalogued as COSV99041552; called by muse, mutect2, varscan2
- DPRX | c.7G>A p.G3S | Missense Mutation (SNP) | VAF 210/216 reads (97%) | SIFT tolerated (0.2); PolyPhen benign (0.354); catalogued as COSV100934094; called by muse, mutect2, varscan2
- DSC3 | c.2605G>A p.E869K | Missense Mutation (SNP) | VAF 171/478 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.777); catalogued as rs866687286, COSV100844559; called by muse, mutect2, varscan2
- DSCAM | c.3745C>T p.P1249S | Missense Mutation (SNP) | VAF 223/468 reads (48%) | SIFT tolerated (0.21); PolyPhen benign (0.197); catalogued as COSV68020410; called by muse, mutect2, varscan2
- DSCAM | c.3604G>A p.A1202T | Missense Mutation (SNP) | VAF 209/463 reads (45%) | SIFT tolerated (0.14); PolyPhen benign (0.096); catalogued as COSV101261697; called by muse, mutect2, varscan2
- DUOX1 | c.1012G>A p.V338I | Missense Mutation (SNP) | VAF 161/275 reads (59%) | SIFT tolerated (0.11); PolyPhen benign (0.065); catalogued as rs767305748, COSV58479095; called by muse, mutect2, varscan2
- DZIP1 | c.1783C>T p.R595* (on ENST00000347108; = p.R576* on NM_014934.5) | Nonsense Mutation (SNP) | VAF 224/449 reads (50%) | catalogued as rs756109756, COSV61263776; called by muse, mutect2, varscan2
- E2F4 | c.472C>T p.R158W | Missense Mutation (SNP) | VAF 261/261 reads (100%) | SIFT deleterious (0.01); PolyPhen benign (0.005); catalogued as rs746229580, COSV58875098; called by muse, mutect2, varscan2
- EFCAB9 | c.418G>A p.E140K | Missense Mutation (SNP) | VAF 179/394 reads (45%) | SIFT tolerated (0.1); PolyPhen benign (0.232); catalogued as rs1200203222; called by muse, mutect2, varscan2
- EFR3B | c.709C>T p.R237W | Missense Mutation (SNP) | VAF 194/482 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV53119301; called by muse, mutect2, varscan2
- EIF4G2 | c.50C>T p.S17L | Missense Mutation (SNP) | VAF 200/280 reads (71%) | SIFT tolerated, low confidence (0.16); PolyPhen possibly damaging (0.885); catalogued as rs1442776478, COSV101151049, COSV60596497; called by muse, mutect2, varscan2
- EIF4G3 | c.2006G>A p.R669Q | Missense Mutation (SNP) | VAF 219/377 reads (58%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.905); catalogued as rs372089216; called by muse, mutect2, varscan2
- EMP1 | c.367C>T p.R123C | Missense Mutation (SNP) | VAF 213/595 reads (36%) | SIFT tolerated (0.17); PolyPhen benign (0.003); catalogued as rs767672209; called by muse, mutect2, varscan2
- EP300 | c.385G>A p.A129T | Missense Mutation (SNP) | VAF 259/532 reads (49%) | SIFT tolerated (0.07); PolyPhen benign (0.168); catalogued as COSV54347351, COSV99606956; called by muse, mutect2, varscan2
- EPB41L5 | c.2101C>T p.P701S | Missense Mutation (SNP) | VAF 104/396 reads (26%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.007); catalogued as rs199753897; called by muse, mutect2, varscan2
- ETV7 | c.1021C>T p.P341S | Missense Mutation (SNP) | VAF 163/434 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV60317132; called by muse, mutect2, varscan2
- EZHIP | c.1241C>T p.P414L | Missense Mutation (SNP) | VAF 379/380 reads (100%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.78); catalogued as rs781925893, COSV57955047; called by muse, mutect2, varscan2
- FAM131B | c.700G>A p.E234K | Missense Mutation (SNP) | VAF 292/468 reads (62%) | SIFT tolerated (0.46); PolyPhen benign (0.038); catalogued as COSV58369943; called by muse, mutect2, varscan2
- FAM135B | c.3506G>A p.G1169E | Missense Mutation (SNP) | VAF 135/746 reads (18%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.994); catalogued as COSV52712378; called by muse, mutect2, varscan2
- FAM135B | c.662C>T p.S221F | Missense Mutation (SNP) | VAF 356/444 reads (80%) | SIFT tolerated (0.1); PolyPhen benign (0.005); catalogued as COSV52725538, COSV52758416; called by muse, mutect2, varscan2
- FAM98A | c.1387G>A p.G463R | Missense Mutation (SNP) | VAF 426/710 reads (60%) | SIFT tolerated, low confidence (0.4); PolyPhen possibly damaging (0.903); catalogued as COSV53212104; called by muse, mutect2, varscan2
- FASN | c.1978G>A p.E660K | Missense Mutation (SNP) | VAF 494/780 reads (63%) | SIFT tolerated (0.62); PolyPhen benign (0.013); catalogued as COSV60756776; called by muse, mutect2, varscan2
- FMN2 | c.3079G>A p.G1027R | Missense Mutation (SNP) | VAF 180/800 reads (23%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.961); catalogued as COSV60445800; called by muse, varscan2
- GABRP | c.992C>T p.S331F | Missense Mutation (SNP) | VAF 194/386 reads (50%) | SIFT tolerated (0.46); PolyPhen possibly damaging (0.79); catalogued as rs1374031679; called by muse, mutect2, varscan2
- GAPT | c.119G>A p.R40Q | Missense Mutation (SNP) | VAF 243/535 reads (45%) | SIFT tolerated (0.53); PolyPhen benign (0.013); catalogued as rs370924428; called by muse, mutect2, varscan2
- GATA6 | c.259C>T p.P87S | Missense Mutation (SNP) | VAF 376/936 reads (40%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.01); catalogued as rs563978220; called by muse, mutect2, varscan2
- GNGT2 | c.98G>A p.G33E | Missense Mutation (SNP) | VAF 84/303 reads (28%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.505); catalogued as rs901763365; called by muse, mutect2, varscan2
- GPC4 | c.1060C>T p.R354C | Missense Mutation (SNP) | VAF 261/261 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV63697091; called by muse, mutect2, varscan2
- GPR142 | c.857C>T p.A286V | Missense Mutation (SNP) | VAF 177/606 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.451); catalogued as COSV100171000; called by muse, mutect2, varscan2
- GPR148 | c.770C>T p.S257F | Missense Mutation (SNP) | VAF 467/656 reads (71%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.946); catalogued as rs1415084072; called by muse, mutect2, varscan2
- GSDME | c.164C>T p.S55F | Missense Mutation (SNP) | VAF 139/356 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV61652298; called by muse, mutect2, varscan2
- H2AC1 | c.217G>A p.D73N | Missense Mutation (SNP) | VAF 323/740 reads (44%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.005); catalogued as COSV51237789; called by muse, mutect2, varscan2
- HAX1 | c.305C>T p.S102F | Missense Mutation (SNP) | VAF 138/257 reads (54%) | SIFT tolerated (0.66); PolyPhen benign (0.428); catalogued as rs1342223114; called by muse, mutect2, varscan2
- HEATR9 | c.253G>A p.D85N | Missense Mutation (SNP) | VAF 157/488 reads (32%) | SIFT tolerated (0.13); PolyPhen benign (0); catalogued as rs1046265812; called by muse, mutect2, varscan2
- HID1 | c.601G>A p.D201N | Missense Mutation (SNP) | VAF 116/379 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.923); catalogued as rs141799560; called by muse, mutect2, varscan2
- HSFX2 | c.148G>A p.D50N | Missense Mutation (SNP) | VAF 228/457 reads (50%) | SIFT tolerated (0.67); PolyPhen benign (0.015); catalogued as rs1464113515; called by muse, mutect2, varscan2
- HTRA3 | c.1324G>A p.D442N | Missense Mutation (SNP) | VAF 130/359 reads (36%) | SIFT tolerated (0.11); PolyPhen benign (0.123); catalogued as rs765049863, COSV56471190; called by muse, mutect2, varscan2
- HYDIN | c.919G>A p.E307K | Missense Mutation (SNP) | VAF 66/166 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as rs868676049, COSV99865696; called by muse, mutect2, varscan2
- IGHV3-13 | c.85G>A p.G29S | Missense Mutation (SNP) | VAF 169/553 reads (31%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.529); catalogued as rs568429833; called by muse, mutect2, varscan2
- IL1B | c.259G>A p.E87K | Missense Mutation (SNP) | VAF 70/323 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.049); catalogued as COSV54522820, COSV99641940; called by muse, mutect2, varscan2
- IPO13 | c.901G>A p.D301N | Missense Mutation (SNP) | VAF 222/496 reads (45%) | SIFT tolerated (0.08); PolyPhen benign (0.113); catalogued as rs1557632190; called by muse, mutect2, varscan2
- ITGA1 | c.394C>G p.P132A | Missense Mutation (SNP) | VAF 134/303 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV50901887; called by muse, mutect2, varscan2
- ITGB4 | c.943G>C p.A315P | Missense Mutation (SNP) | VAF 333/481 reads (69%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.849); catalogued as COSV52333019; called by muse, mutect2, varscan2
- ITGB4 | c.1210G>A p.E404K | Missense Mutation (SNP) | VAF 85/243 reads (35%) | SIFT tolerated (0.14); PolyPhen benign (0.038); catalogued as rs886053409, COSV52322502, COSV52324788, COSV52332573; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- KCND2 | c.1718G>A p.R573Q | Missense Mutation (SNP) | VAF 66/166 reads (40%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.862); catalogued as rs761446789, COSV58602956; called by muse, mutect2, varscan2
- KCNH5 | c.155G>A p.G52E | Missense Mutation (SNP) | VAF 106/252 reads (42%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.951); catalogued as COSV59757775; called by muse, mutect2, varscan2
- KCNQ3 | c.2080G>A p.E694K | Missense Mutation (SNP) | VAF 687/837 reads (82%) | SIFT tolerated (0.83); PolyPhen benign (0.01); catalogued as rs766760025; called by muse, mutect2, varscan2
- KIF3B | c.551C>T p.T184I | Missense Mutation (SNP) | VAF 116/307 reads (38%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.727); catalogued as rs769441232; called by muse, mutect2, varscan2
- KIR3DL1 | c.356G>A p.G119E | Missense Mutation (SNP) | VAF 55/122 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.944); catalogued as COSV58494612; called by muse, mutect2, varscan2
- KLHL4 | c.863G>A p.R288Q | Missense Mutation (SNP) | VAF 211/211 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as rs190477338, COSV64139169; called by muse, mutect2, varscan2
- LAMB4 | c.3053C>T p.T1018I | Missense Mutation (SNP) | VAF 80/246 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.767); catalogued as rs754812469; called by muse, mutect2, varscan2
- LCP2 | c.320C>T p.S107F | Missense Mutation (SNP) | VAF 190/394 reads (48%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.969); catalogued as rs1197342170; called by muse, mutect2, varscan2
- LCT | c.3761G>A p.R1254Q | Missense Mutation (SNP) | VAF 115/502 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs201664009, COSV51545585; called by muse, mutect2, varscan2
- LINGO2 | c.1700G>A p.S567N | Missense Mutation (SNP) | VAF 100/206 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100430074; called by muse, mutect2, varscan2
- LMAN1L | c.901G>A p.G301R | Missense Mutation (SNP) | VAF 86/235 reads (37%) | SIFT tolerated (0.37); PolyPhen benign (0.039); catalogued as rs1191894246; called by muse, mutect2, varscan2
- LRRC72 | c.517C>T p.Q173* | Nonsense Mutation (SNP) | VAF 127/210 reads (60%) | catalogued as rs780558703, COSV69130958; called by muse, mutect2, varscan2
- LTBP2 | c.4851G>A p.W1617* | Nonsense Mutation (SNP) | VAF 208/340 reads (61%) | catalogued as COSV56211672; called by muse, varscan2
- LTBP2 | c.2320C>T p.R774W | Missense Mutation (SNP) | VAF 396/579 reads (68%) | SIFT deleterious (0.01); PolyPhen benign (0.045); catalogued as rs763665239, COSV100001208; called by muse, mutect2, varscan2
- LY6K | c.355C>T p.R119C | Missense Mutation (SNP) | VAF 608/744 reads (82%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.732); catalogued as rs1172467075, COSV52832110; called by muse, mutect2, varscan2
- MBD5 | c.1873C>T p.P625S | Missense Mutation (SNP) | VAF 288/399 reads (72%) | SIFT tolerated (0.11); PolyPhen benign (0.019); catalogued as rs749574412, COSV68698339; called by muse, mutect2, varscan2
- MECOM | c.217G>A p.D73N | Missense Mutation (SNP) | VAF 226/226 reads (100%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs761171278, COSV72110504; called by muse, mutect2, varscan2
- MED14 | c.3631C>T p.L1211F | Missense Mutation (SNP) | VAF 217/217 reads (100%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.996); catalogued as COSV61357419; called by muse, mutect2, varscan2
- MED26 | c.316G>A p.G106R | Missense Mutation (SNP) | VAF 362/376 reads (96%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1467486702; called by muse, mutect2, varscan2
- MGAM | c.160C>T p.P54S | Missense Mutation (SNP) | VAF 138/380 reads (36%) | SIFT tolerated (0.36); PolyPhen benign (0); catalogued as COSV101516333; called by muse, mutect2, varscan2
- MGAM2 | c.3306G>A p.M1102I | Missense Mutation (SNP) | VAF 90/275 reads (33%) | SIFT tolerated (0.1); PolyPhen benign (0.053); catalogued as rs867532916, COSV101522919; called by muse, mutect2, varscan2
- MIB1 | c.1786G>T p.G596* | Nonsense Mutation (SNP) | VAF 187/519 reads (36%) | catalogued as rs1555694075; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- MMP16 | c.1709C>T p.P570L | Missense Mutation (SNP) | VAF 168/1035 reads (16%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.942); catalogued as rs553868301, COSV54154651; called by muse, mutect2, varscan2
- MPDZ | c.985G>A p.V329I | Missense Mutation (SNP) | VAF 132/276 reads (48%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs375346024; called by muse, mutect2, varscan2
- MTMR8 | c.1749G>A p.M583I | Missense Mutation (SNP) | VAF 356/357 reads (100%) | SIFT tolerated (0.05); PolyPhen benign (0.005); catalogued as rs775189398; called by muse, mutect2, varscan2
- MTSS1 | c.400C>T p.R134C | Missense Mutation (SNP) | VAF 391/467 reads (84%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.631); catalogued as rs1361280992, COSV61494478; called by muse, mutect2
- MUC16 | c.25978C>T p.P8660S | Missense Mutation (SNP) | VAF 18/396 reads (5%) | SIFT tolerated, low confidence (0.46); PolyPhen benign (0.065); catalogued as rs1568797505; called by muse, mutect2
- MUC16 | c.25187C>T p.S8396F | Missense Mutation (SNP) | VAF 247/265 reads (93%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.865); catalogued as COSV101198768; called by muse, mutect2, varscan2
- MUC16 | c.14974G>A p.D4992N | Missense Mutation (SNP) | VAF 12/248 reads (5%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0.093); catalogued as COSV67492491; called by muse, mutect2
- MUC20 | c.1084C>T p.R362W | Missense Mutation (SNP) | VAF 104/466 reads (22%) | SIFT tolerated, low confidence (0.1); catalogued as rs1425538927; called by muse, varscan2
- MYCL | c.563C>T p.T188I | Missense Mutation (SNP) | VAF 239/481 reads (50%) | SIFT deleterious (0.02); PolyPhen benign (0.204); catalogued as rs1312202445; called by muse, mutect2, varscan2
- MYL2 | c.392C>T p.S131F | Missense Mutation (SNP) | VAF 148/433 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.912); catalogued as COSV57405879; called by muse, mutect2, varscan2
- MYO3B | c.2198C>T p.S733L | Missense Mutation (SNP) | VAF 105/418 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs866879141, COSV100509399, COSV58714099; called by muse, mutect2, varscan2
- MYO9B | c.4015C>T p.R1339W | Missense Mutation (SNP) | VAF 368/385 reads (96%) | SIFT deleterious (0.03); PolyPhen benign (0.019); catalogued as rs748214669; called by muse, mutect2, varscan2
- NAGA | c.268C>T p.R90C | Missense Mutation (SNP) | VAF 317/755 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.57); catalogued as rs773683396; called by muse, mutect2, varscan2
- NEXMIF | c.1961C>T p.S654L | Missense Mutation (SNP) | VAF 262/262 reads (100%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.982); catalogued as rs267606511, COSV50045459, COSV99280638; called by muse, mutect2, varscan2
- NF1 | c.140C>T p.S47F | Missense Mutation (SNP) | VAF 88/256 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV62217982; called by muse, mutect2, varscan2
- NFKBID | c.523C>T p.P175S (on ENST00000396901; = p.P327S on NM_032721.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 351/366 reads (96%) | SIFT tolerated (0.23); PolyPhen benign (0.009); catalogued as COSV61728273; called by muse, mutect2, varscan2
- NLRP4 | c.1636G>A p.G546R | Missense Mutation (SNP) | VAF 368/378 reads (97%) | SIFT tolerated (0.51); PolyPhen benign (0.003); catalogued as rs1314897163; called by muse, mutect2, varscan2
- NME8 | c.274G>A p.G92S | Missense Mutation (SNP) | VAF 73/177 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); catalogued as COSV52251728; called by muse, mutect2, varscan2
- NRXN1 | c.616G>A p.D206N | Missense Mutation (SNP) | VAF 249/651 reads (38%) | SIFT tolerated (0.5); PolyPhen benign (0.007); catalogued as rs200781129, COSV68032996, COSV99065640; called by muse, mutect2, varscan2
- OCM2 | c.160G>A p.D54N | Missense Mutation (SNP) | VAF 130/349 reads (37%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs747093318, COSV57535115; called by muse, mutect2, varscan2
- OOSP1 | c.157G>A p.D53N | Missense Mutation (SNP) | VAF 181/327 reads (55%) | SIFT tolerated (0.17); PolyPhen benign (0.089); catalogued as rs1000134920, COSV67527450; called by muse, mutect2, varscan2
- OPRD1 | c.824C>T p.A275V | Missense Mutation (SNP) | VAF 448/770 reads (58%) | SIFT deleterious (0.05); PolyPhen benign (0.108); catalogued as rs139895939; called by muse, varscan2
- OR10X1 | c.628C>T p.H210Y | Missense Mutation (SNP) | VAF 203/541 reads (38%) | SIFT tolerated (0.44); PolyPhen benign (0); catalogued as COSV100936720; called by muse, mutect2, varscan2
- OR11A1 | c.20G>A p.G7E | Missense Mutation (SNP) | VAF 199/491 reads (41%) | SIFT tolerated (0.4); PolyPhen benign (0.006); catalogued as COSV65820757; called by muse, mutect2, varscan2
- OR13A1 | c.971C>T p.P324L | Missense Mutation (SNP) | VAF 150/150 reads (100%) | SIFT tolerated (0.09); PolyPhen benign (0.003); catalogued as COSV65573428; called by muse, mutect2, varscan2
- OR2F1 | c.200C>T p.S67F | Missense Mutation (SNP) | VAF 271/470 reads (58%) | SIFT deleterious (0); PolyPhen possibly damaging (0.907); catalogued as COSV67332099; called by muse, mutect2, varscan2
- OR2Y1 | c.542C>T p.P181L | Missense Mutation (SNP) | VAF 248/493 reads (50%) | SIFT tolerated (0.07); PolyPhen benign (0.058); catalogued as COSV57137608, COSV57137765; called by muse, mutect2, varscan2
- OR51G1 | c.673C>T p.R225C | Missense Mutation (SNP) | VAF 111/290 reads (38%) | SIFT deleterious (0.02); PolyPhen benign (0.009); catalogued as rs200001303; called by muse, mutect2, varscan2
- OR5M8 | c.61G>A p.E21K | Missense Mutation (SNP) | VAF 110/374 reads (29%) | SIFT deleterious (0.02); PolyPhen benign (0.176); catalogued as COSV59116574; called by muse, mutect2, varscan2
- OR6F1 | c.503T>C p.F168S | Missense Mutation (SNP) | VAF 228/526 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1254250084; called by muse, mutect2, varscan2
- OSBPL6 | c.1051G>A p.D351N | Missense Mutation (SNP) | VAF 122/489 reads (25%) | SIFT tolerated (0.33); PolyPhen benign (0.165); catalogued as COSV51920128, COSV99506400; called by muse, mutect2, varscan2
- OSM | c.514G>A p.A172T | Missense Mutation (SNP) | VAF 226/458 reads (49%) | SIFT tolerated (0.72); PolyPhen benign (0); catalogued as rs200481037; called by muse, mutect2, varscan2
- OTOF | c.3440G>A p.R1147Q (on ENST00000272371 / NM_194248.3; = p.R400Q on NM_004802.4) | Missense Mutation (SNP) | VAF 277/451 reads (61%) | SIFT deleterious (0); PolyPhen possibly damaging (0.674); catalogued as rs369188910; called by muse, mutect2, varscan2
- PAPPA | c.4447G>A p.E1483K | Missense Mutation (SNP) | VAF 137/269 reads (51%) | SIFT tolerated (0.2); PolyPhen benign (0); catalogued as rs775634573, COSV60282314; called by muse, mutect2, varscan2
- PCDH18 | c.851C>T p.S284F | Missense Mutation (SNP) | VAF 200/200 reads (100%) | SIFT deleterious (0); PolyPhen possibly damaging (0.884); catalogued as COSV100787463; called by muse, mutect2, varscan2
- PCDH9 | c.2384C>T p.P795L | Missense Mutation (SNP) | VAF 195/423 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as COSV60532348, COSV60586640; called by muse, mutect2, varscan2
- PCDHA11 | c.1058C>T p.S353F | Missense Mutation (SNP) | VAF 296/590 reads (50%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.524); catalogued as rs745813666, COSV56485626; called by muse, mutect2, varscan2
- PCLO | c.12768G>A p.M4256I | Missense Mutation (SNP) | VAF 204/333 reads (61%) | SIFT tolerated (0.06); PolyPhen benign (0.003); catalogued as rs1362193454, COSV100433963, COSV61630371; called by muse, mutect2, varscan2
- PCLO | c.2642C>T p.P881L | Missense Mutation (SNP) | VAF 275/422 reads (65%) | SIFT tolerated (0.05); PolyPhen benign (0.155); catalogued as rs745329573; called by muse, mutect2, varscan2
- PDILT | c.1069G>A p.E357K | Missense Mutation (SNP) | VAF 14/282 reads (5%) | SIFT tolerated (0.21); PolyPhen benign (0.031); catalogued as rs1373532778, COSV56703412; called by muse, mutect2
- PIK3C3 | c.734C>T p.P245L | Missense Mutation (SNP) | VAF 182/312 reads (58%) | SIFT tolerated (0.21); PolyPhen benign (0.03); catalogued as COSV56275479; called by muse, mutect2, varscan2
- PIP5K1A | c.542C>T p.S181F (on ENST00000368888 / NM_001135638.2; = p.S168F on NM_003557.3) | Missense Mutation (SNP) | VAF 158/340 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); catalogued as COSV62958287; called by muse, mutect2, varscan2
- PKD1L3 | c.1591C>T p.Q531* | Nonsense Mutation (SNP) | VAF 244/244 reads (100%) | catalogued as rs1223335178; called by muse, mutect2, varscan2
- PLAAT3 | c.155C>T p.S52F | Missense Mutation (SNP) | VAF 108/343 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as rs1490350309; called by muse, mutect2, varscan2
- PLCE1 | c.262G>A p.E88K | Missense Mutation (SNP) | VAF 418/418 reads (100%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.321); catalogued as COSV53369010, COSV99593235; called by muse, mutect2, varscan2
- PRB3 | c.283C>T p.R95C | Missense Mutation (SNP) | VAF 368/970 reads (38%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.798); catalogued as rs148496066; called by muse, varscan2
- PRDM1 | c.793G>A p.D265N | Missense Mutation (SNP) | VAF 274/275 reads (100%) | SIFT tolerated (0.18); PolyPhen benign (0.003); catalogued as rs1385182753, COSV64844396; called by muse, mutect2, varscan2
- PRKACG | c.698C>T p.A233V | Missense Mutation (SNP) | VAF 192/336 reads (57%) | SIFT tolerated (0.18); PolyPhen benign (0.013); catalogued as COSV55253800; called by muse, mutect2, varscan2
- PRKAR1B | c.1088C>T p.S363F | Missense Mutation (SNP) | VAF 196/196 reads (100%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.754); catalogued as COSV64319132; called by muse, mutect2, varscan2
- PSG5 | c.563C>T p.P188L | Missense Mutation (SNP) | VAF 80/668 reads (12%) | SIFT tolerated (0.11); PolyPhen benign (0.045); catalogued as rs536362682, COSV61654604; called by muse, mutect2
- PTCHD3 | c.2227G>A p.E743K | Missense Mutation (SNP) | VAF 248/248 reads (100%) | SIFT tolerated (0.34); PolyPhen benign (0.365); catalogued as rs868028770, COSV101438955; called by muse, mutect2, varscan2
- PTGS1 | c.1267G>A p.D423N | Missense Mutation (SNP) | VAF 124/261 reads (48%) | SIFT tolerated (0.09); PolyPhen benign (0.03); catalogued as COSV56293163; called by muse, mutect2, varscan2
- PTPRF | c.1250C>T p.P417L | Missense Mutation (SNP) | VAF 354/836 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs17849128; called by muse, varscan2
- RAB3IP | c.527G>A p.R176Q (on ENST00000550536 / NM_175623.4; = p.R160Q on NM_022456.5) | Missense Mutation (SNP) | VAF 175/175 reads (100%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.978); catalogued as rs756835019, COSV56082842, COSV56085195; called by muse, mutect2, varscan2
- RBL2 | c.3293C>T p.P1098L | Missense Mutation (SNP) | VAF 195/195 reads (100%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.722); catalogued as rs77016789; called by muse, mutect2, varscan2
- RBPJL | c.325C>T p.Q109* | Nonsense Mutation (SNP) | VAF 203/351 reads (58%) | catalogued as rs756771074, COSV59213830; called by muse, mutect2, varscan2
- RGS7 | c.1147G>A p.E383K | Missense Mutation (SNP) | VAF 203/463 reads (44%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.768); catalogued as rs866505496, COSV58531455; called by muse, mutect2, varscan2
- RICTOR | c.79C>T p.P27S | Missense Mutation (SNP) | VAF 233/482 reads (48%) | SIFT tolerated (0.05); PolyPhen benign (0.005); catalogued as rs980024517, COSV57125411; called by muse, varscan2
- RIMBP2 | c.736G>A p.E246K | Missense Mutation (SNP) | VAF 295/433 reads (68%) | SIFT tolerated (0.08); PolyPhen benign (0.427); catalogued as rs1248114269, COSV55478093, COSV55481546; called by muse, mutect2, varscan2
- ROS1 | c.3121C>T p.P1041S | Missense Mutation (SNP) | VAF 134/134 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1185167609; called by muse, mutect2, varscan2
- RP1 | c.5069C>T p.S1690L | Missense Mutation (SNP) | VAF 130/1018 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.354); catalogued as rs750964056, COSV55129263; called by muse, mutect2
- RP1 | c.1138C>T p.P380S | Missense Mutation (SNP) | VAF 279/739 reads (38%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.591); catalogued as rs751446958; called by muse, mutect2, varscan2
- RUNDC3B | c.769C>T p.P257S | Missense Mutation (SNP) | VAF 120/342 reads (35%) | SIFT tolerated (0.2); PolyPhen benign (0.05); catalogued as COSV100406927; called by muse, varscan2
- RYR3 | c.12975G>A p.Q4325= (on ENST00000389232; = p.Q4326= on NM_001036.6) | Splice Region (SNP) | VAF 104/160 reads (65%) | catalogued as COSV101213054; called by muse, mutect2, varscan2
- SCN5A | c.4321G>A p.E1441K (on ENST00000333535 / NM_198056.3; = p.E1440K on NM_000335.5) | Missense Mutation (SNP) | VAF 111/248 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.726); catalogued as CM100727, COSV100349357; called by muse, mutect2, varscan2
- SERPINA11 | c.915C>T p.P305= | Splice Region (SNP) | VAF 139/200 reads (70%) | catalogued as rs1477080621; called by muse, mutect2, varscan2
- SERPINB4 | c.729G>A p.M243I | Missense Mutation (SNP) | VAF 180/507 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV61985829; called by muse, mutect2, varscan2
- SEZ6L2 | c.1027C>T p.P343S (on ENST00000308713 / NM_001114099.3; = p.P273S on NM_012410.4) | Missense Mutation (SNP) | VAF 203/441 reads (46%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs1057335935; called by muse, mutect2, varscan2
- SIMC1 | c.254C>T p.S85F (on ENST00000443967 / NM_001308196.1; = p.S104F on NM_001308195.2) | Missense Mutation (SNP) | VAF 244/484 reads (50%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.902); catalogued as COSV100365228; called by muse, mutect2, varscan2
- SLC30A8 | c.383C>T p.P128L | Missense Mutation (SNP) | VAF 467/562 reads (83%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.942); catalogued as rs753601826; called by muse, mutect2, varscan2
- SLC4A9 | c.2377G>A p.E793K (on ENST00000507527 / NM_001258428.2; = p.E769K on NM_031467.3) | Missense Mutation (SNP) | VAF 269/494 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs764257656, COSV50189820; called by muse, mutect2, varscan2
- SLC5A11 | c.1897G>A p.E633K | Missense Mutation (SNP) | VAF 21/336 reads (6%) | SIFT tolerated (0.5); PolyPhen benign (0.001); catalogued as rs1426701225; called by muse, mutect2
- SLC8A3 | c.812G>A p.R271Q | Missense Mutation (SNP) | VAF 128/390 reads (33%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.992); catalogued as rs148642634; called by muse, mutect2, varscan2
- SNX21 | c.139G>A p.D47N | Missense Mutation (SNP) | VAF 449/703 reads (64%) | SIFT tolerated (0.11); PolyPhen benign (0.414); catalogued as rs775236284; called by muse, mutect2, varscan2
- SPANXN4 | c.28G>A p.E10K | Missense Mutation (SNP) | VAF 186/187 reads (99%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.007); catalogued as rs1031927543, COSV100980951; called by muse, mutect2, varscan2
- SPATA31D1 | c.2294C>T p.S765F | Missense Mutation (SNP) | VAF 161/321 reads (50%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.935); catalogued as rs368073850; called by muse, mutect2, varscan2
- SPHKAP | c.4379C>T p.S1460L | Missense Mutation (SNP) | VAF 129/507 reads (25%) | SIFT tolerated (0.37); PolyPhen benign (0); catalogued as rs368612893, COSV60876685; called by muse, mutect2, varscan2
- SPHKAP | c.1577C>T p.S526L | Missense Mutation (SNP) | VAF 387/522 reads (74%) | SIFT deleterious (0.04); PolyPhen benign (0.003); catalogued as rs760510406, COSV60893705; called by muse, mutect2, varscan2
- SPRR3 | c.109A>C p.T37P | Missense Mutation (SNP) | VAF 212/559 reads (38%) | SIFT deleterious (0.03); PolyPhen benign (0.144); catalogued as COSV54878872; called by muse, mutect2, varscan2
- SPTA1 | c.6229G>A p.E2077K | Missense Mutation (SNP) | VAF 443/720 reads (62%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV63752052; called by muse, mutect2, varscan2
- TAL1 | c.881C>T p.S294F | Missense Mutation (SNP) | VAF 405/744 reads (54%) | SIFT deleterious (0); PolyPhen possibly damaging (0.841); catalogued as rs765173173; called by muse, mutect2, varscan2
- TEP1 | c.5839C>T p.R1947* | Nonsense Mutation (SNP) | VAF 235/368 reads (64%) | catalogued as rs200869389; called by muse, mutect2, varscan2
- TGM1 | c.1043G>A p.R348Q | Missense Mutation (SNP) | VAF 141/398 reads (35%) | SIFT tolerated (0.31); PolyPhen benign (0.3); catalogued as rs201379408, COSV99253270; called by muse, mutect2, varscan2
- THOC3 | c.926C>T p.P309L | Missense Mutation (SNP) | VAF 103/448 reads (23%) | SIFT tolerated (0.07); PolyPhen benign (0.021); catalogued as rs774666886; called by muse, mutect2, varscan2
- TIMD4 | c.643C>T p.P215S | Missense Mutation (SNP) | VAF 152/333 reads (46%) | SIFT tolerated (0.29); PolyPhen benign (0.005); catalogued as rs867787194; called by muse, mutect2, varscan2
- TINAG | c.1081G>A p.E361K | Missense Mutation (SNP) | VAF 119/205 reads (58%) | SIFT deleterious (0); PolyPhen benign (0.239); catalogued as rs771554711, COSV52506168; called by muse, mutect2, varscan2
- TLL1 | c.1561G>A p.E521K | Missense Mutation (SNP) | VAF 77/254 reads (30%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.622); catalogued as rs150728189, COSV50304665; called by muse, mutect2, varscan2
- TLR2 | c.140C>T p.P47L | Missense Mutation (SNP) | VAF 255/379 reads (67%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52605411; called by muse, mutect2, varscan2
- TMEM260 | c.1469G>A p.R490Q | Missense Mutation (SNP) | VAF 189/365 reads (52%) | SIFT tolerated (0.29); PolyPhen possibly damaging (0.749); catalogued as rs961346366; called by muse, mutect2, varscan2
- TMPPE | c.344C>T p.S115F | Missense Mutation (SNP) | VAF 294/570 reads (52%) | SIFT deleterious (0); PolyPhen possibly damaging (0.571); catalogued as rs1365997473, COSV56566058; called by muse, mutect2, varscan2
- TNFRSF11B | c.97G>A p.E33K | Missense Mutation (SNP) | VAF 116/578 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0); catalogued as rs202090603, COSV52071162; called by muse, mutect2, varscan2
- TNN | c.1657C>T p.P553S | Missense Mutation (SNP) | VAF 147/337 reads (44%) | SIFT tolerated (0.13); PolyPhen benign (0.217); catalogued as rs756576017, COSV53429664; called by muse, varscan2
- TNRC18 | c.5276C>T p.S1759F | Missense Mutation (SNP) | VAF 248/439 reads (56%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.781); catalogued as rs1333874250; called by muse, mutect2, varscan2
- TPTE | c.796G>A p.E266K (on ENST00000618007 / NM_199261.4; = p.E248K on NM_199259.4) | Missense Mutation (SNP) | VAF 96/361 reads (27%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.688); catalogued as rs1328516038; called by muse, mutect2, varscan2
- TRAT1 | c.443C>T p.S148F | Missense Mutation (SNP) | VAF 251/252 reads (100%) | SIFT deleterious (0); PolyPhen benign (0.428); catalogued as COSV55469879, COSV55470893; called by muse, mutect2, varscan2
- TRERF1 | c.1373G>A p.G458E | Missense Mutation (SNP) | VAF 374/929 reads (40%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.005); catalogued as COSV61674258; called by muse, mutect2, varscan2
- TRGC1 | c.508G>A p.G170R | Missense Mutation (SNP) | VAF 125/485 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.63); catalogued as rs1052400124; called by muse, mutect2
- TRPM3 | c.2845G>A p.D949N (on ENST00000357533 / NM_001366142.2; = p.D792N on NM_020952.6) | Missense Mutation (SNP) | VAF 110/306 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV62580612; called by muse, mutect2, varscan2
- TRPV6 | c.817G>A p.D273N | Missense Mutation (SNP) | VAF 218/568 reads (38%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.506); catalogued as COSV63892080; called by muse, mutect2, varscan2
- TTN | c.32326G>A p.E10776K (on ENST00000591111; = p.E9849K on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 234/362 reads (65%) | PolyPhen probably damaging (0.991); catalogued as rs1223983021, COSV59862637; called by muse, mutect2
- TUBG1 | c.1124G>A p.G375E | Missense Mutation (SNP) | VAF 266/455 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs111345251; called by muse, mutect2, varscan2
- UBR4 | c.10000G>A p.A3334T | Missense Mutation (SNP) | VAF 216/423 reads (51%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0); catalogued as rs766096673; called by muse, mutect2, varscan2
- USP4 | c.2387C>T p.P796L | Missense Mutation (SNP) | VAF 124/272 reads (46%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.803); catalogued as rs758676462; called by muse, mutect2, varscan2
- VCX | c.514G>A p.E172K | Missense Mutation (SNP) | VAF 180/629 reads (29%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.931); catalogued as rs1569093120; called by muse, varscan2
- ZBP1 | c.331G>A p.E111K | Missense Mutation (SNP) | VAF 175/268 reads (65%) | SIFT tolerated (0.21); PolyPhen benign (0.029); catalogued as rs764212417, COSV100472931; called by muse, mutect2, varscan2
- ZC3H11B | c.263G>A p.R88Q | Missense Mutation (SNP) | VAF 40/392 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.981); catalogued as rs1281222562; called by muse, mutect2
- ZC3H13 | c.2680C>T p.R894C | Missense Mutation (SNP) | VAF 217/494 reads (44%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as rs760598611, COSV104387510, COSV54457977; called by muse, mutect2, varscan2
- ZMYM3 | c.302G>A p.G101E | Missense Mutation (SNP) | VAF 425/425 reads (100%) | SIFT tolerated, low confidence (0.33); PolyPhen benign (0.001); catalogued as rs779781647; called by muse, mutect2, varscan2
- ZNF208 | c.3319C>T p.H1107Y | Missense Mutation (SNP) | VAF 176/181 reads (97%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.99); catalogued as rs267605384; called by muse, mutect2, varscan2
- ZNF43 | c.922C>T p.H308Y | Missense Mutation (SNP) | VAF 117/117 reads (100%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.877); catalogued as rs1355975743, COSV61685142; called by muse, mutect2, varscan2
- ZNF432 | c.1351C>T p.H451Y | Missense Mutation (SNP) | VAF 385/399 reads (96%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as rs1298344417, COSV55415218; called by muse, mutect2, varscan2
- ZNF479 | c.817G>A p.E273K | Missense Mutation (SNP) | VAF 188/364 reads (52%) | SIFT tolerated (0.06); PolyPhen benign (0.125); catalogued as rs782624607; called by muse, mutect2, varscan2
- ZNF696 | c.8C>T p.P3L | Missense Mutation (SNP) | VAF 463/578 reads (80%) | SIFT tolerated, low confidence (1); PolyPhen possibly damaging (0.713); catalogued as rs1371700038; called by muse, mutect2, varscan2
- ZNF804A | c.1825G>A p.E609K | Missense Mutation (SNP) | VAF 74/341 reads (22%) | SIFT tolerated (0.11); PolyPhen benign (0.001); catalogued as rs1465760741, COSV56470507; called by muse, mutect2, varscan2
- ZNF827 | c.3124C>T p.L1042F | Missense Mutation (SNP) | VAF 122/398 reads (31%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); catalogued as COSV101061221; called by muse, mutect2, varscan2
- ZNF835 | c.1040C>T p.S347L | Missense Mutation (SNP) | VAF 448/472 reads (95%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.963); catalogued as COSV73379159; called by muse, mutect2
- A3GALT2 | c.92G>A p.G31D | Missense Mutation (SNP) | VAF 186/394 reads (47%) | SIFT tolerated (0.08); PolyPhen benign (0.413); called by muse, varscan2
- ABCA12 | c.6117G>A p.M2039I (on ENST00000272895 / NM_173076.3; = p.M1721I on NM_015657.3) | Missense Mutation (SNP) | VAF 166/231 reads (72%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.472); called by muse, mutect2, varscan2
- ABCG1 | c.1907C>T p.A636V | Missense Mutation (SNP) | VAF 230/485 reads (47%) | SIFT tolerated (0.1); PolyPhen benign (0.062); called by muse, mutect2, varscan2
- AC099489.1 | c.1964C>A p.T655K | Missense Mutation (SNP) | VAF 301/326 reads (92%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.797); called by muse, mutect2
- ADAMTS10 | c.1415C>T p.A472V | Missense Mutation (SNP) | VAF 19/322 reads (6%) | SIFT tolerated (1); PolyPhen possibly damaging (0.623); called by muse, mutect2
- ADAMTS16 | c.2179G>A p.G727R | Missense Mutation (SNP) | VAF 162/345 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ADAMTSL3 | c.862_867dup p.V288_F289dup | In Frame Ins (INS) | VAF 90/279 reads (32%) | called by mutect2, pindel, varscan2
- ADRA1B | c.997G>A p.V333M | Missense Mutation (SNP) | VAF 212/499 reads (42%) | SIFT deleterious (0); PolyPhen benign (0.145); called by muse, mutect2, varscan2
- AKAP13 | c.1313C>T p.S438F | Missense Mutation (SNP) | VAF 267/402 reads (66%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- AKAP4 | c.2513T>G p.V838G | Missense Mutation (SNP) | VAF 326/326 reads (100%) | SIFT deleterious (0); PolyPhen possibly damaging (0.509); called by muse, mutect2, varscan2
- ALMS1 | c.28_35delinsTACGTGCTGGA p.G10_L12delinsYVLE | In Frame Ins (INS) | VAF 7/78 reads (9%) | called by muse*, pindel, varscan2*
- ALMS1 | c.437C>T p.S146F | Missense Mutation (SNP) | VAF 62/175 reads (35%) | SIFT deleterious (0.04); PolyPhen benign (0.222); called by muse, mutect2, varscan2
- ALOXE3 | c.1686T>C p.G562= | Splice Region (SNP) | VAF 127/127 reads (100%) | called by muse, mutect2, varscan2
- ANKRD24 | c.890G>A p.G297E | Missense Mutation (SNP) | VAF 20/402 reads (5%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2
- ANKS1B | c.2625G>A p.K875= (on ENST00000547776 / NM_152788.4; = p.K101= on NM_020140.3 and 1 other RefSeq transcript) | Splice Region (SNP) | VAF 139/139 reads (100%) | called by muse, mutect2, varscan2
- APLP1 | c.1627C>T p.P543S (on ENST00000221891 / NM_001024807.3; = p.P542S on NM_005166.4) | Missense Mutation (SNP) | VAF 17/341 reads (5%) | SIFT tolerated (0.49); PolyPhen benign (0.003); called by muse, mutect2
- APOB | c.11425C>T p.P3809S | Missense Mutation (SNP) | VAF 124/378 reads (33%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.952); called by muse, mutect2, varscan2
- APOB | c.10235G>A p.S3412N | Missense Mutation (SNP) | VAF 240/398 reads (60%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.853); called by muse, mutect2, varscan2
- ARHGAP10 | c.1897A>C p.T633P | Missense Mutation (SNP) | VAF 182/273 reads (67%) | SIFT deleterious (0.05); PolyPhen benign (0); called by muse, mutect2, varscan2
- ARHGAP21 | c.2944C>T p.P982S | Missense Mutation (SNP) | VAF 156/171 reads (91%) | SIFT tolerated (0.41); PolyPhen benign (0.053); called by muse, mutect2, varscan2
- ARSD | c.1778C>T p.P593L | Missense Mutation (SNP) | VAF 113/113 reads (100%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.637); called by muse, mutect2, varscan2
- ASXL2 | c.1811T>C p.F604S | Missense Mutation (SNP) | VAF 226/352 reads (64%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- B3GALT5 | c.710C>T p.P237L | Missense Mutation (SNP) | VAF 278/547 reads (51%) | SIFT tolerated (0.07); PolyPhen benign (0.405); called by muse, mutect2, varscan2
- BARX2 | c.710C>T p.S237F | Missense Mutation (SNP) | VAF 193/538 reads (36%) | SIFT tolerated (0.07); PolyPhen benign (0); called by muse, mutect2, varscan2
- BECN2 | c.956C>T p.S319L | Missense Mutation (SNP) | VAF 336/586 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.94); called by muse, mutect2, varscan2
- BIN1 | c.1682G>A p.G561D (on ENST00000316724 / NM_001320642.1; = p.G422D on NM_004305.4) | Missense Mutation (SNP) | VAF 303/418 reads (72%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- BRD8 | c.1361C>T p.S454F (on ENST00000254900 / NM_139199.2; = p.S527F on NM_006696.4) | Missense Mutation (SNP) | VAF 246/491 reads (50%) | SIFT deleterious (0); PolyPhen possibly damaging (0.795); called by muse, mutect2, varscan2
- BSN | c.3965C>T p.S1322F | Missense Mutation (SNP) | VAF 339/709 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.921); called by muse, mutect2, varscan2
- C16orf96 | c.350C>T p.P117L | Missense Mutation (SNP) | VAF 32/356 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- C5AR2 | c.809T>A p.L270Q | Missense Mutation (SNP) | VAF 21/582 reads (4%) | SIFT tolerated (0.63); PolyPhen benign (0.42); called by muse, mutect2
- CA1 | c.331G>A p.D111N | Missense Mutation (SNP) | VAF 64/569 reads (11%) | SIFT tolerated (0.15); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CACNA1I | c.5243C>T p.A1748V | Missense Mutation (SNP) | VAF 327/892 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.913); called by muse, mutect2, varscan2
- CASP3 | c.788C>T p.P263L | Missense Mutation (SNP) | VAF 187/274 reads (68%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CC2D1A | c.1376C>T p.P459L | Missense Mutation (SNP) | VAF 22/378 reads (6%) | SIFT deleterious (0.03); PolyPhen benign (0.003); called by muse, mutect2
- CD101 | c.841G>A p.V281M | Missense Mutation (SNP) | VAF 113/245 reads (46%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.72); called by muse, mutect2, varscan2
- CD163L1 | c.1927G>A p.G643R | Missense Mutation (SNP) | VAF 239/736 reads (32%) | SIFT tolerated (0.34); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- CD55 | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 178/438 reads (41%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.444); called by muse, mutect2, varscan2
- CDSN | c.1501G>A p.D501N | Missense Mutation (SNP) | VAF 373/992 reads (38%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- CEP104 | c.262C>T p.Q88* | Nonsense Mutation (SNP) | VAF 137/329 reads (42%) | called by muse, mutect2, varscan2
- CHL1 | c.856G>A p.E286K (on ENST00000397491 / NM_001253387.1; = p.E302K on NM_006614.4) | Missense Mutation (SNP) | VAF 203/407 reads (50%) | SIFT tolerated (0.86); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- CLEC18B | c.893C>T p.P298L | Missense Mutation (SNP) | VAF 75/403 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- CLN5 | c.122G>A p.W41* | Nonsense Mutation (SNP) | VAF 381/767 reads (50%) | called by muse, mutect2, varscan2
- CNGB3 | c.398A>T p.H133L | Missense Mutation (SNP) | VAF 127/936 reads (14%) | SIFT deleterious (0.02); PolyPhen benign (0.368); called by muse, mutect2, varscan2
- CNST | c.832A>T p.K278* | Nonsense Mutation (SNP) | VAF 30/90 reads (33%) | called by muse, mutect2, varscan2
- CNTN4 | c.1182T>G p.F394L | Missense Mutation (SNP) | VAF 59/289 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.284); called by muse, mutect2, varscan2
- COL12A1 | c.2450C>T p.P817L | Missense Mutation (SNP) | VAF 148/151 reads (98%) | SIFT deleterious (0.01); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- COL18A1 | c.5137G>C p.A1713P (on ENST00000359759 / NM_130444.3; = p.A1478P on NM_030582.4) | Missense Mutation (SNP) | VAF 371/759 reads (49%) | SIFT tolerated (0.25); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- COL20A1 | c.1579G>A p.E527K | Missense Mutation (SNP) | VAF 315/514 reads (61%) | SIFT tolerated (0.59); PolyPhen benign (0.253); called by muse, mutect2, varscan2
- COL6A2 | c.449G>A p.S150N | Missense Mutation (SNP) | VAF 342/695 reads (49%) | SIFT tolerated (0.16); PolyPhen benign (0.054); called by muse, mutect2, varscan2
- CREB3 | c.917G>A p.G306D | Missense Mutation (SNP) | VAF 181/344 reads (53%) | SIFT tolerated (0.14); PolyPhen benign (0.039); called by muse, mutect2, varscan2
- CREBBP | c.6923C>T p.P2308L | Missense Mutation (SNP) | VAF 619/654 reads (95%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.118); called by muse, mutect2, varscan2
- CREBBP | c.6922C>T p.P2308S | Missense Mutation (SNP) | VAF 622/657 reads (95%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- CRNN | c.661C>T p.H221Y | Missense Mutation (SNP) | VAF 345/686 reads (50%) | SIFT tolerated (0.2); PolyPhen benign (0.25); called by muse, mutect2, varscan2
- DDX60L | c.3586G>A p.E1196K | Missense Mutation (SNP) | VAF 195/291 reads (67%) | SIFT tolerated (0.19); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- DEF6 | c.96G>A p.K32= | Splice Region (SNP) | VAF 172/481 reads (36%) | called by muse, mutect2, varscan2
- DLK1 | c.907C>T p.Q303* | Nonsense Mutation (SNP) | VAF 343/524 reads (65%) | called by muse, mutect2, varscan2
- DNAH1 | c.11407G>A p.D3803N | Missense Mutation (SNP) | VAF 214/427 reads (50%) | SIFT tolerated (0.16); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- DNAH10 | c.2414G>A p.G805E (on ENST00000409039; = p.G744E on NM_207437.3) | Missense Mutation (SNP) | VAF 67/211 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- DNAH10 | c.13162G>A p.G4388R (on ENST00000409039; = p.G4327R on NM_207437.3) | Missense Mutation (SNP) | VAF 270/433 reads (62%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- DNAH5 | c.5011G>A p.E1671K | Missense Mutation (SNP) | VAF 217/451 reads (48%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.77); called by muse, mutect2, varscan2
- DNAH7 | c.9073G>A p.E3025K | Missense Mutation (SNP) | VAF 76/294 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- DNAJB8 | c.346G>A p.D116N | Missense Mutation (SNP) | VAF 277/277 reads (100%) | SIFT tolerated (0.07); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- DZIP1 | c.1369C>T p.P457S | Missense Mutation (SNP) | VAF 102/222 reads (46%) | SIFT tolerated (0.55); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ENDOV | c.586-8T>G | Splice Region (SNP) | VAF 875/1264 reads (69%) | called by muse, mutect2, varscan2
- ETV5 | c.1231C>T p.Q411* | Nonsense Mutation (SNP) | VAF 126/126 reads (100%) | called by muse, mutect2, varscan2
- EYA1 | c.1003G>C p.V335L | Missense Mutation (SNP) | VAF 104/673 reads (15%) | SIFT tolerated (0.07); PolyPhen benign (0.043); called by muse, mutect2, varscan2
- FAM120A | c.2999G>A p.G1000D | Missense Mutation (SNP) | VAF 99/196 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- FAT3 | c.11002G>A p.G3668R | Missense Mutation (SNP) | VAF 138/404 reads (34%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.735); called by muse, mutect2, varscan2
- FBLN2 | c.26G>A p.G9E | Missense Mutation (SNP) | VAF 276/636 reads (43%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- FCGR2A | c.140C>T p.P47L (on ENST00000271450 / NM_001136219.3; = p.P46L on NM_021642.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 225/638 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- FIGNL2 | c.1661A>G p.Y554C | Missense Mutation (SNP) | VAF 489/504 reads (97%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- FIZ1 | c.596C>T p.P199L | Missense Mutation (SNP) | VAF 534/553 reads (97%) | SIFT deleterious (0.04); PolyPhen benign (0); called by muse, mutect2, varscan2
- FKBP1C | c.116C>T p.S39F | Missense Mutation (SNP) | VAF 163/522 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- FLT4 | c.1369C>T p.Q457* | Nonsense Mutation (SNP) | VAF 264/542 reads (49%) | called by muse, varscan2
- GOLGA6L6 | c.1291G>A p.E431K | Missense Mutation (SNP) | VAF 33/97 reads (34%) | SIFT deleterious (0.04); PolyPhen benign (0.133); called by muse, mutect2, varscan2
- GPBAR1 | c.616G>A p.V206M | Missense Mutation (SNP) | VAF 216/773 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- GPBP1L1 | c.190+1G>A p.X64_splice | Splice Site (SNP) | VAF 134/240 reads (56%) | called by muse, mutect2, varscan2
- GRAMD2A | c.874G>A p.E292K | Missense Mutation (SNP) | VAF 273/416 reads (66%) | SIFT tolerated (0.14); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- GTF3C1 | c.4483C>T p.P1495S | Missense Mutation (SNP) | VAF 12/344 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- HCFC1 | c.4448C>T p.A1483V | Missense Mutation (SNP) | VAF 409/409 reads (100%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.734); called by muse, mutect2, varscan2
- HDAC10 | c.370A>C p.N124H | Missense Mutation (SNP) | VAF 163/305 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- HDAC11 | c.106C>T p.P36S | Missense Mutation (SNP) | VAF 242/491 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- HDGFL1 | c.598G>A p.A200T | Missense Mutation (SNP) | VAF 625/1060 reads (59%) | SIFT deleterious (0.02); PolyPhen benign (0.088); called by muse, varscan2
- HEATR5B | c.3112C>T p.H1038Y | Missense Mutation (SNP) | VAF 182/327 reads (56%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.968); called by muse, mutect2, varscan2
- HECW2 | c.4456G>A p.E1486K | Missense Mutation (SNP) | VAF 290/395 reads (73%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- HIPK4 | c.224T>A p.F75Y | Missense Mutation (SNP) | VAF 317/341 reads (93%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.589); called by muse, mutect2, varscan2
- HMCN2 | c.14686C>T p.P4896S | Missense Mutation (SNP) | VAF 130/265 reads (49%) | SIFT tolerated (0.18); PolyPhen benign (0.283); called by muse, mutect2, varscan2
- HNRNPUL1 | c.406G>C p.A136P | Missense Mutation (SNP) | VAF 198/236 reads (84%) | SIFT tolerated (0.32); PolyPhen benign (0.043); called by muse, mutect2, varscan2
- HSD3B1 | c.310G>A p.G104S | Missense Mutation (SNP) | VAF 136/210 reads (65%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.819); called by muse, mutect2, varscan2
- ICE1 | c.1689del p.F563Lfs*42 | Frame Shift Del (DEL) | VAF 208/522 reads (40%) | called by mutect2, pindel, varscan2
- IDH3B | c.874C>T p.P292S | Missense Mutation (SNP) | VAF 227/386 reads (59%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.943); called by muse, mutect2, varscan2
- IL1RAPL1 | c.228G>A p.W76* | Nonsense Mutation (SNP) | VAF 325/325 reads (100%) | called by muse, mutect2, varscan2
- IMPDH2 | c.1135C>T p.L379F | Missense Mutation (SNP) | VAF 155/330 reads (47%) | SIFT deleterious (0.01); PolyPhen benign (0.35); called by muse, mutect2, varscan2
- INPP5E | c.97G>A p.A33T | Missense Mutation (SNP) | VAF 223/494 reads (45%) | SIFT tolerated, low confidence (0.59); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- INSYN2B | c.932C>T p.S311F | Missense Mutation (SNP) | VAF 214/418 reads (51%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.735); called by muse, mutect2, varscan2
- INTS2 | c.3496G>A p.D1166N | Missense Mutation (SNP) | VAF 178/402 reads (44%) | SIFT tolerated, low confidence (0.47); PolyPhen benign (0.354); called by muse, mutect2, varscan2
- IPO5 | c.578C>T p.S193F | Missense Mutation (SNP) | VAF 114/258 reads (44%) | SIFT deleterious (0); PolyPhen benign (0.396); called by muse, mutect2, varscan2
- ITK | c.316C>T p.L106F | Missense Mutation (SNP) | VAF 137/340 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ITPR3 | c.844C>T p.L282F | Missense Mutation (SNP) | VAF 215/560 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- KCNB1 | c.1517C>T p.T506I | Missense Mutation (SNP) | VAF 286/455 reads (63%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.077); called by muse, mutect2, varscan2
- KCNJ2 | c.1231C>T p.Q411* | Nonsense Mutation (SNP) | VAF 211/342 reads (62%) | called by muse, mutect2, varscan2
- KIAA2012 | c.742C>T p.P248S | Missense Mutation (SNP) | VAF 398/537 reads (74%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- KYNU | c.395C>T p.A132V | Missense Mutation (SNP) | VAF 89/181 reads (49%) | SIFT tolerated (0.37); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- L1TD1 | c.604G>A p.D202N | Missense Mutation (SNP) | VAF 155/360 reads (43%) | SIFT tolerated (0.64); PolyPhen benign (0); called by muse, mutect2, varscan2
- LARP1B | c.496C>T p.P166S | Missense Mutation (SNP) | VAF 107/107 reads (100%) | SIFT tolerated (0.31); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- LCORL | c.4565G>A p.R1522K | Missense Mutation (SNP) | VAF 88/285 reads (31%) | SIFT tolerated (0.35); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- LMBRD2 | c.263C>T p.P88L | Missense Mutation (SNP) | VAF 125/277 reads (45%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.824); called by muse, mutect2, varscan2
- LPAR4 | c.1087G>A p.E363K | Missense Mutation (SNP) | VAF 180/181 reads (99%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- LRRC3 | c.239del p.P80Rfs*81 | Frame Shift Del (DEL) | VAF 345/862 reads (40%) | called by mutect2, pindel, varscan2
- LRRC53 | c.3154A>G p.T1052A | Missense Mutation (SNP) | VAF 235/424 reads (55%) | SIFT tolerated (0.21); PolyPhen benign (0.224); called by muse, mutect2, varscan2
- LRRC75B | c.321G>A p.W107* | Nonsense Mutation (SNP) | VAF 98/207 reads (47%) | called by muse, mutect2, varscan2
- LRRC75B | c.320G>A p.W107* | Nonsense Mutation (SNP) | VAF 97/206 reads (47%) | called by muse, mutect2, varscan2
- LTBP2 | c.4850G>A p.W1617* | Nonsense Mutation (SNP) | VAF 232/371 reads (63%) | called by muse, mutect2, varscan2
- LY6G6F-LY6G6D | c.494C>T p.P165L | Missense Mutation (SNP) | VAF 201/1098 reads (18%) | SIFT tolerated (0.16); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- MBD5 | c.91C>T p.Q31* | Nonsense Mutation (SNP) | VAF 230/339 reads (68%) | called by muse, mutect2, varscan2
- MDH1B | c.1393C>T p.Q465* | Nonsense Mutation (SNP) | VAF 77/327 reads (24%) | called by muse, mutect2, varscan2
- MED26 | c.317G>A p.G106E | Missense Mutation (SNP) | VAF 364/377 reads (97%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- MEGF9 | c.988G>A p.E330K | Missense Mutation (SNP) | VAF 101/208 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- MEIOC | c.2041C>A p.Q681K | Missense Mutation (SNP) | VAF 211/306 reads (69%) | SIFT tolerated (0.1); PolyPhen benign (0.318); called by muse, mutect2, varscan2
- MEOX1 | c.338C>T p.S113F | Missense Mutation (SNP) | VAF 164/837 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.723); called by muse, mutect2, varscan2
- MGA | c.6767T>C p.V2256A (on ENST00000219905 / NM_001164273.1; = p.V2047A on NM_001080541.2) | Missense Mutation (SNP) | VAF 196/310 reads (63%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0.079); called by muse, mutect2, varscan2
- MGAM2 | c.394C>T p.Q132* | Nonsense Mutation (SNP) | VAF 212/357 reads (59%) | called by muse, mutect2, varscan2
- MGAM2 | c.5632C>T p.P1878S | Missense Mutation (SNP) | VAF 237/384 reads (62%) | SIFT tolerated, low confidence (0.12); called by muse, mutect2, varscan2
- MLLT10 | c.3202A>C p.S1068R | Missense Mutation (SNP) | VAF 220/220 reads (100%) | SIFT deleterious (0); PolyPhen benign (0.224); called by muse, mutect2, varscan2
- MOG | c.155C>T p.P52L | Missense Mutation (SNP) | VAF 354/884 reads (40%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.968); called by muse, mutect2, varscan2
- MSH2 | c.107T>G p.L36R | Missense Mutation (SNP) | VAF 251/700 reads (36%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.567); called by muse, mutect2, varscan2
- MSLN | c.646G>A p.D216N | Missense Mutation (SNP) | VAF 300/632 reads (47%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.84); called by muse, mutect2, varscan2
- MTBP | c.2113C>T p.L705F | Missense Mutation (SNP) | VAF 229/572 reads (40%) | SIFT deleterious (0.03); PolyPhen benign (0.139); called by muse, mutect2, varscan2
- MTX2 | c.592G>A p.G198R | Missense Mutation (SNP) | VAF 82/319 reads (26%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.977); called by muse, mutect2, varscan2
- MUC12 | c.9190G>C p.E3064Q (on ENST00000379442; = p.E2921Q on NM_001164462.1) | Missense Mutation (SNP) | VAF 275/897 reads (31%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.736); called by muse, mutect2, varscan2
- MUC16 | c.42264T>A p.Y14088* | Nonsense Mutation (SNP) | VAF 217/228 reads (95%) | called by muse, mutect2, varscan2
- MXRA5 | c.2435C>T p.S812F | Missense Mutation (SNP) | VAF 375/376 reads (100%) | SIFT tolerated (0.2); PolyPhen benign (0.231); called by muse, varscan2
- MYO15B | c.7949G>A p.G2650E | Missense Mutation (SNP) | VAF 118/370 reads (32%) | SIFT tolerated (0.72); PolyPhen benign (0.149); called by muse, mutect2
- NCAPG2 | c.2738T>A p.M913K | Missense Mutation (SNP) | VAF 94/263 reads (36%) | SIFT deleterious (0); PolyPhen benign (0.345); called by muse, mutect2, varscan2
- NCOA6 | c.2215G>A p.G739R | Missense Mutation (SNP) | VAF 169/438 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- NIF3L1 | c.109T>G p.L37V (on ENST00000409020 / NM_001369444.1; = p.L10V on NM_021824.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 127/484 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- NOS1 | c.1775G>A p.W592* | Nonsense Mutation (SNP) | VAF 114/387 reads (29%) | called by muse, mutect2, varscan2
- NPHS1 | c.2956C>T p.H986Y | Missense Mutation (SNP) | VAF 14/335 reads (4%) | SIFT tolerated (0.08); PolyPhen benign (0.033); called by muse, mutect2
- NT5C1B | c.1651A>C p.T551P (on ENST00000359846 / NM_001199086.2; = p.T491P on NM_033253.4) | Missense Mutation (SNP) | VAF 339/534 reads (63%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- NTRK3 | c.788T>C p.V263A | Missense Mutation (SNP) | VAF 208/317 reads (66%) | SIFT tolerated (0.75); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- NUMA1 | c.5751G>A p.W1917* | Nonsense Mutation (SNP) | VAF 264/396 reads (67%) | called by muse, mutect2, varscan2
- OR2F1 | c.827T>A p.V276D | Missense Mutation (SNP) | VAF 142/364 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.639); called by muse, mutect2, varscan2
- OR4A47 | c.829del p.T277Pfs*4 | Frame Shift Del (DEL) | VAF 195/577 reads (34%) | called by mutect2, pindel, varscan2
- OR6J1 | c.472C>T p.P158S | Missense Mutation (SNP) | VAF 137/333 reads (41%) | SIFT tolerated (0.15); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- OR9A4 | c.232C>T p.P78S | Missense Mutation (SNP) | VAF 288/441 reads (65%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- PCDH9 | c.2383C>T p.P795S | Missense Mutation (SNP) | VAF 194/422 reads (46%) | SIFT tolerated (0.05); PolyPhen benign (0.401); called by muse, mutect2, varscan2
- PCDHB12 | c.886C>T p.Q296* | Nonsense Mutation (SNP) | VAF 159/342 reads (46%) | called by muse, mutect2, varscan2
- PEG3 | c.589C>T p.L197F | Missense Mutation (SNP) | VAF 261/270 reads (97%) | SIFT deleterious (0); PolyPhen benign (0.198); called by muse, mutect2, varscan2
- PGAP4 | c.248T>C p.L83P | Missense Mutation (SNP) | VAF 163/310 reads (53%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.6); called by muse, mutect2, varscan2
- PGAP6 | c.860G>A p.G287E | Missense Mutation (SNP) | VAF 292/560 reads (52%) | SIFT tolerated (0.14); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- PGAP6 | c.859G>C p.G287R | Missense Mutation (SNP) | VAF 294/565 reads (52%) | SIFT tolerated (0.07); PolyPhen benign (0.022); called by muse, mutect2, varscan2
- PIWIL2 | c.1318G>A p.D440N | Missense Mutation (SNP) | VAF 192/192 reads (100%) | SIFT tolerated (0.07); PolyPhen benign (0.02); called by muse, mutect2, varscan2
- PKP2 | c.1309A>T p.N437Y | Missense Mutation (SNP) | VAF 356/602 reads (59%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.547); called by muse, mutect2, varscan2
- PLA2G4D | c.370T>A p.F124I | Missense Mutation (SNP) | VAF 111/165 reads (67%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.883); called by muse, mutect2, varscan2
- PLCG1 | c.1748T>C p.F583S | Missense Mutation (SNP) | VAF 155/408 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PLEKHG3 | c.3178C>T p.P1060S (on ENST00000394691; = p.P1116S on NM_001308147.2) | Missense Mutation (SNP) | VAF 156/501 reads (31%) | SIFT tolerated (0.22); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- PLIN1 | c.1357C>T p.R453C | Missense Mutation (SNP) | VAF 214/577 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- PLXNA1 | c.1453C>T p.P485S | Missense Mutation (SNP) | VAF 342/342 reads (100%) | SIFT tolerated (0.05); PolyPhen benign (0.03); called by muse, mutect2, varscan2
- PNPLA6 | c.862G>A p.A288T (on ENST00000414982 / NM_001166111.2; = p.A240T on NM_006702.5) | Missense Mutation (SNP) | VAF 313/328 reads (95%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- POM121C | c.659G>A p.G220E | Missense Mutation (SNP) | VAF 564/725 reads (78%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- PPP1R9B | c.2439T>G p.N813K | Missense Mutation (SNP) | VAF 272/412 reads (66%) | SIFT tolerated (1); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- PROKR1 | c.151G>A p.D51N | Missense Mutation (SNP) | VAF 162/471 reads (34%) | SIFT tolerated (0.11); PolyPhen benign (0.184); called by muse, mutect2, varscan2
- PWWP2B | c.1700T>C p.I567T | Missense Mutation (SNP) | VAF 354/354 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- PXDN | c.1813G>A p.V605M | Missense Mutation (SNP) | VAF 218/352 reads (62%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.934); called by muse, mutect2
- PYHIN1 | c.369C>A p.N123K | Missense Mutation (SNP) | VAF 189/608 reads (31%) | SIFT tolerated (1); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- PZP | c.2336C>T p.S779F | Missense Mutation (SNP) | VAF 410/680 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- RBAK | c.1613C>T p.S538F | Missense Mutation (SNP) | VAF 192/348 reads (55%) | SIFT deleterious (0); PolyPhen benign (0.28); called by muse, mutect2, varscan2
- RBBP5 | c.1334C>T p.S445F | Missense Mutation (SNP) | VAF 244/529 reads (46%) | SIFT deleterious (0.04); PolyPhen benign (0.019); called by muse, mutect2, varscan2
- RBMS3 | c.1112C>T p.A371V (on ENST00000383767 / NM_001003793.3; = p.A355V on NM_014483.3) | Missense Mutation (SNP) | VAF 144/330 reads (44%) | SIFT tolerated (0.11); PolyPhen benign (0.022); called by muse, mutect2
- RC3H2 | c.2234T>C p.V745A | Missense Mutation (SNP) | VAF 10/196 reads (5%) | SIFT tolerated (0.25); PolyPhen benign (0.003); called by muse, mutect2
- RFTN1 | c.941T>C p.L314S | Missense Mutation (SNP) | VAF 250/503 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- RGS7BP | c.331G>A p.G111S | Missense Mutation (SNP) | VAF 142/279 reads (51%) | SIFT tolerated, low confidence (0.18); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- RMDN2 | c.101G>T p.G34V | Missense Mutation (SNP) | VAF 92/261 reads (35%) | SIFT tolerated (0.17); PolyPhen benign (0.167); called by muse, mutect2, varscan2
- RNF180 | c.1637G>A p.R546K | Missense Mutation (SNP) | VAF 201/375 reads (54%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.758); called by muse, mutect2, varscan2
- RNF24 | c.379C>T p.Q127* | Nonsense Mutation (SNP) | VAF 150/417 reads (36%) | called by muse, mutect2, varscan2
- RPAP2 | c.688G>A p.G230R | Missense Mutation (SNP) | VAF 157/361 reads (43%) | SIFT tolerated (0.2); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- RPAP2 | c.689G>A p.G230E | Missense Mutation (SNP) | VAF 159/365 reads (44%) | SIFT tolerated (0.16); PolyPhen benign (0.055); called by muse, mutect2, varscan2
- RUNDC3B | c.770C>T p.P257L | Missense Mutation (SNP) | VAF 132/370 reads (36%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.77); called by muse, mutect2, varscan2
- SCN11A | c.262C>T p.H88Y | Missense Mutation (SNP) | VAF 68/146 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.878); called by muse, mutect2, varscan2
- SELENOV | c.751C>A p.P251T | Missense Mutation (SNP) | VAF 380/413 reads (92%) | SIFT tolerated (0.1); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- SENP1 | c.205C>T p.P69S | Missense Mutation (SNP) | VAF 175/445 reads (39%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- SERPINB11 | c.1109C>T p.P370L | Missense Mutation (SNP) | VAF 384/634 reads (61%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SERPING1 | c.719C>T p.S240F | Missense Mutation (SNP) | VAF 226/361 reads (63%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- SIRT4 | c.785C>T p.S262F | Missense Mutation (SNP) | VAF 56/189 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); called by muse, mutect2, varscan2
- SLC36A1 | c.344A>C p.D115A | Missense Mutation (SNP) | VAF 237/469 reads (51%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.964); called by muse, mutect2, varscan2
- SLC5A8 | c.14G>A p.R5Q | Missense Mutation (SNP) | VAF 316/317 reads (100%) | SIFT tolerated (0.42); PolyPhen benign (0.058); called by muse, mutect2, varscan2
- SLFN12L | c.1346C>T p.S449F (on ENST00000260908 / NM_001363830.1; = p.S467F on NM_001195790.1) | Missense Mutation (SNP) | VAF 265/414 reads (64%) | SIFT deleterious (0); PolyPhen benign (0.432); called by muse, mutect2, varscan2
- SON | c.4981G>A p.A1661T | Missense Mutation (SNP) | VAF 217/432 reads (50%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.824); called by muse, mutect2, varscan2
- SPATA9 | c.56G>A p.G19E | Missense Mutation (SNP) | VAF 161/391 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SPEN | c.7576G>A p.D2526N | Missense Mutation (SNP) | VAF 287/526 reads (55%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SPINK5 | c.1024G>A p.E342K | Missense Mutation (SNP) | VAF 131/248 reads (53%) | SIFT tolerated (0.16); PolyPhen benign (0.05); called by muse, mutect2, varscan2
- SRD5A3 | c.626T>A p.M209K | Missense Mutation (SNP) | VAF 147/423 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.844); called by muse, mutect2, varscan2
- SRM | c.629A>G p.Q210R | Missense Mutation (SNP) | VAF 111/462 reads (24%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.602); called by muse, mutect2, varscan2
- STAB1 | c.5524G>A p.D1842N | Missense Mutation (SNP) | VAF 266/548 reads (49%) | SIFT tolerated (0.46); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- SUCLG2 | c.1195G>A p.E399K | Missense Mutation (SNP) | VAF 88/171 reads (51%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.567); called by muse, mutect2, varscan2
- SVEP1 | c.9173A>G p.H3058R | Missense Mutation (SNP) | VAF 134/271 reads (49%) | SIFT tolerated (0.4); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- SYCP1 | c.2456C>T p.T819I | Missense Mutation (SNP) | VAF 167/403 reads (41%) | SIFT deleterious (0.01); PolyPhen benign (0.044); called by muse, mutect2, varscan2
- SYCP2L | c.1471G>A p.D491N | Missense Mutation (SNP) | VAF 230/567 reads (41%) | SIFT tolerated (0.47); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- TAOK3 | c.2371C>T p.Q791* | Nonsense Mutation (SNP) | VAF 190/292 reads (65%) | called by muse, mutect2, varscan2
- TAP2 | c.1775T>C p.M592T | Missense Mutation (SNP) | VAF 250/621 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.676); called by muse, mutect2, varscan2
- TCF12 | c.491C>T p.S164F | Missense Mutation (SNP) | VAF 95/293 reads (32%) | SIFT deleterious (0); PolyPhen benign (0.276); called by muse, mutect2, varscan2
- TDRD15 | c.923G>A p.G308E | Missense Mutation (SNP) | VAF 103/301 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TEAD2 | c.908G>A p.W303* | Nonsense Mutation (SNP) | VAF 180/195 reads (92%) | called by muse, mutect2, varscan2
- TENM2 | c.1118G>A p.W373* (on ENST00000518659 / NM_001122679.2; = p.W182* on NM_001080428.3) | Nonsense Mutation (SNP) | VAF 260/547 reads (48%) | called by muse, mutect2, varscan2
- TENM4 | c.1190C>T p.S397F | Missense Mutation (SNP) | VAF 195/322 reads (61%) | SIFT deleterious (0.01); PolyPhen benign (0.365); called by muse, mutect2, varscan2
- TFEB | c.995C>T p.S332F | Missense Mutation (SNP) | VAF 483/806 reads (60%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.964); called by muse, varscan2
- TLR2 | c.959C>T p.P320L | Missense Mutation (SNP) | VAF 175/266 reads (66%) | SIFT tolerated (0.1); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- TM2D3 | c.284C>T p.P95L (on ENST00000333202 / NM_078474.3; = p.P69L on NM_025141.3) | Missense Mutation (SNP) | VAF 157/267 reads (59%) | SIFT tolerated (0.06); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- TMEM132C | c.2194G>A p.D732N | Missense Mutation (SNP) | VAF 107/337 reads (32%) | SIFT tolerated (0.07); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TMEM18 | c.134C>T p.S45F | Missense Mutation (SNP) | VAF 132/316 reads (42%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.93); called by muse, varscan2
- TMPRSS13 | c.1187C>T p.S396F | Missense Mutation (SNP) | VAF 164/476 reads (34%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.978); called by muse, mutect2, varscan2
- TNKS1BP1 | c.4957C>T p.P1653S | Missense Mutation (SNP) | VAF 103/318 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- TOGARAM1 | c.3151C>T p.P1051S | Missense Mutation (SNP) | VAF 65/261 reads (25%) | SIFT tolerated (0.19); PolyPhen benign (0.066); called by muse, mutect2, varscan2
- TRANK1 | c.4302C>A p.F1434L | Missense Mutation (SNP) | VAF 197/463 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- TRIM71 | c.2227C>T p.L743F | Missense Mutation (SNP) | VAF 287/571 reads (50%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.915); called by muse, mutect2, varscan2
- TTN | c.24031C>T p.H8011Y (on ENST00000591111; = p.H7084Y on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 326/444 reads (73%) | PolyPhen benign (0.037); called by muse, mutect2, varscan2
- UNC5A | c.667G>A p.A223T | Missense Mutation (SNP) | VAF 367/728 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- USP35 | c.685C>T p.P229S | Missense Mutation (SNP) | VAF 92/310 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, varscan2
- VAT1L | c.803C>T p.P268L | Missense Mutation (SNP) | VAF 171/171 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- VCAN | c.709G>A p.E237K | Missense Mutation (SNP) | VAF 130/276 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- VWCE | c.2746C>T p.L916F | Missense Mutation (SNP) | VAF 380/571 reads (67%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- VWDE | c.2156A>G p.K719R | Missense Mutation (SNP) | VAF 212/345 reads (61%) | SIFT tolerated (0.51); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- WASHC2C | c.3950C>T p.A1317V (on ENST00000336378; = p.A1296V on NM_015262.3 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 274/292 reads (94%) | SIFT tolerated (0.09); PolyPhen benign (0.073); called by muse, mutect2, varscan2
- WASL | c.554C>T p.T185I | Missense Mutation (SNP) | VAF 156/245 reads (64%) | SIFT tolerated (0.18); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- WNK1 | c.3631G>C p.G1211R (on ENST00000315939 / NM_018979.4; = p.G964R on NM_014823.3) | Missense Mutation (SNP) | VAF 183/465 reads (39%) | SIFT tolerated (0.06); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- WNK1 | c.4900C>T p.H1634Y (on ENST00000315939 / NM_018979.4; = p.H1387Y on NM_014823.3) | Missense Mutation (SNP) | VAF 389/648 reads (60%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.715); called by muse, mutect2, varscan2
- XPO5 | c.2860C>T p.Q954* | Nonsense Mutation (SNP) | VAF 227/596 reads (38%) | called by muse, mutect2, varscan2
- XYLB | c.809C>T p.P270L | Missense Mutation (SNP) | VAF 192/431 reads (45%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.598); called by muse, mutect2, varscan2
- ZC3H3 | c.1742C>T p.P581L | Missense Mutation (SNP) | VAF 535/689 reads (78%) | SIFT deleterious (0.05); PolyPhen benign (0.254); called by muse, mutect2, varscan2
- ZNF233 | c.416C>T p.S139F | Missense Mutation (SNP) | VAF 17/306 reads (6%) | SIFT tolerated (0.09); PolyPhen benign (0.157); called by muse, mutect2
- ZNF484 | c.1595C>T p.S532L | Missense Mutation (SNP) | VAF 104/232 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.809); called by muse, mutect2, varscan2
- ZNF658 | c.614A>G p.H205R | Missense Mutation (SNP) | VAF 88/150 reads (59%) | SIFT tolerated (0.06); PolyPhen benign (0.278); called by muse, mutect2, varscan2
- ZNF729 | c.3231A>T p.K1077N | Missense Mutation (SNP) | VAF 49/199 reads (25%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ZNF74 | c.1175C>T p.S392F | Missense Mutation (SNP) | VAF 189/411 reads (46%) | SIFT deleterious (0); PolyPhen benign (0.085); called by muse, mutect2, varscan2
- ZP2 | c.676G>A p.G226R | Missense Mutation (SNP) | VAF 13/245 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- ZSCAN23 | c.625C>T p.L209F | Missense Mutation (SNP) | VAF 349/608 reads (57%) | SIFT tolerated (0.72); PolyPhen benign (0.047); called by muse, mutect2, varscan2
- ZW10 | c.467T>G p.L156* | Nonsense Mutation (SNP) | VAF 165/277 reads (60%) | called by muse, mutect2, varscan2
- ABCC3 | c.831G>A p.G277= | Silent (SNP) | VAF 151/446 reads (34%) | catalogued as COSV53327288; called by muse, mutect2, varscan2
- ABL2 | c.720C>T p.T240= (on ENST00000502732 / NM_007314.4; = p.T225= on NM_005158.5) | Silent (SNP) | VAF 141/282 reads (50%) | called by muse, mutect2, varscan2
- ACOD1 | c.1125G>C p.P375= | Silent (SNP) | VAF 230/485 reads (47%) | called by muse, mutect2, varscan2
- ACSBG2 | c.1014C>T p.S338= | Silent (SNP) | VAF 257/278 reads (92%) | catalogued as COSV53127040; called by muse, mutect2, varscan2
- ADCK2 | c.282C>T p.F94= | Silent (SNP) | VAF 280/793 reads (35%) | catalogued as COSV50782657; called by muse, mutect2, varscan2
- ADGRG4 | c.8712C>T p.L2904= | Silent (SNP) | VAF 216/216 reads (100%) | called by muse, mutect2, varscan2
- AFDN | c.4026T>C p.R1342= | Silent (SNP) | VAF 295/295 reads (100%) | called by muse, mutect2, varscan2
- AFF1 | c.1492C>T p.L498= | Silent (SNP) | VAF 71/207 reads (34%) | catalogued as COSV100320963, COSV57121125; called by muse, mutect2, varscan2
- ANKRD17 | c.2493G>A p.Q831= | Silent (SNP) | VAF 224/354 reads (63%) | called by muse, mutect2, varscan2
- APOB | c.1053G>A p.L351= | Silent (SNP) | VAF 121/334 reads (36%) | called by muse, mutect2, varscan2
- ARHGEF26 | c.2184G>A p.K728= | Silent (SNP) | VAF 275/275 reads (100%) | called by muse, mutect2, varscan2
- ARSD | c.1779C>T p.P593= | Silent (SNP) | VAF 109/109 reads (100%) | called by muse, mutect2, varscan2
- ATP5F1A | c.993C>T p.P331= | Silent (SNP) | VAF 170/480 reads (35%) | catalogued as rs1452723710; called by muse, mutect2, varscan2
- C4orf54 | c.4479G>A p.E1493= | Silent (SNP) | VAF 280/446 reads (63%) | catalogued as rs1274125688; called by muse, mutect2, varscan2
- CACNA1G | c.4734C>A p.S1578= | Silent (SNP) | VAF 135/427 reads (32%) | catalogued as rs767434117, COSV61724511; called by muse, mutect2, varscan2
- CAV3 | c.447G>A p.K149= | Silent (SNP) | VAF 158/330 reads (48%) | catalogued as rs1455578834; called by muse, mutect2, varscan2
- CCDC168 | c.13311G>A p.E4437= | Silent (SNP) | VAF 197/389 reads (51%) | called by muse, mutect2, varscan2
- CEP95 | c.1173T>C p.G391= | Silent (SNP) | VAF 108/218 reads (50%) | called by muse, mutect2, varscan2
- CFAP92 | c.2409C>T p.F803= | Silent (SNP) | VAF 272/272 reads (100%) | called by muse, mutect2, varscan2
- CFAP92 | c.1497G>A p.R499= | Silent (SNP) | VAF 271/272 reads (100%) | called by muse, mutect2, varscan2
- CHGA | c.900C>T p.S300= | Silent (SNP) | VAF 99/278 reads (36%) | called by muse, mutect2, varscan2
- CHRNA1 | c.1155G>A p.K385= (on ENST00000261007 / NM_001039523.3; = p.K360= on NM_000079.4) | Silent (SNP) | VAF 112/400 reads (28%) | catalogued as COSV53684435, COSV99650570; called by muse, mutect2, varscan2
- CIR1 | c.66C>T p.I22= | Silent (SNP) | VAF 214/319 reads (67%) | called by muse, mutect2, varscan2
- CNTNAP4 | c.573C>T p.S191= | Silent (SNP) | VAF 153/153 reads (100%) | called by muse, mutect2, varscan2
- COL4A4 | c.4434C>T p.P1478= | Silent (SNP) | VAF 155/573 reads (27%) | catalogued as rs1343679990; called by muse, mutect2, varscan2
- CP | c.192G>A p.G64= | Silent (SNP) | VAF 122/122 reads (100%) | catalogued as COSV52828957; called by muse, mutect2, varscan2
- CPD | c.1584C>T p.S528= | Silent (SNP) | VAF 94/288 reads (33%) | called by muse, mutect2, varscan2
- CPT1A | c.1062G>A p.L354= | Silent (SNP) | VAF 140/427 reads (33%) | catalogued as rs764880445, COSV99681790; called by muse, mutect2, varscan2
- CRTC2 | c.1066C>T p.L356= | Silent (SNP) | VAF 279/632 reads (44%) | called by muse, mutect2, varscan2
- CSMD2 | c.1824C>T p.I608= | Silent (SNP) | VAF 236/441 reads (54%) | catalogued as COSV53968367; called by muse, mutect2, varscan2
- CTNNB1 | c.765C>T p.A255= | Silent (SNP) | VAF 156/341 reads (46%) | called by muse, mutect2, varscan2
- CYP4F11 | c.858C>T p.F286= | Silent (SNP) | VAF 242/257 reads (94%) | catalogued as COSV56126107; called by muse, mutect2, varscan2
- CYTIP | c.105G>A p.T35= | Silent (SNP) | VAF 340/482 reads (71%) | catalogued as rs760586360; called by muse, mutect2, varscan2
- DELE1 | c.684C>T p.S228= | Silent (SNP) | VAF 174/348 reads (50%) | called by muse, mutect2, varscan2
- DIRAS3 | c.621G>A p.Q207= | Silent (SNP) | VAF 232/429 reads (54%) | called by muse, mutect2, varscan2
- DNAH10 | c.9975G>T p.L3325= (on ENST00000409039; = p.L3264= on NM_207437.3) | Silent (SNP) | VAF 208/335 reads (62%) | called by muse, mutect2, varscan2
- DNAH10 | c.13161G>A p.S4387= (on ENST00000409039; = p.S4326= on NM_207437.3) | Silent (SNP) | VAF 270/427 reads (63%) | catalogued as rs370675426; called by muse, mutect2, varscan2
- DNAH17 | c.3003T>C p.F1001= | Silent (SNP) | VAF 256/399 reads (64%) | catalogued as rs775466290; called by muse, mutect2, varscan2
- DNAH5 | c.10761C>T p.S3587= | Silent (SNP) | VAF 233/509 reads (46%) | catalogued as rs1156933558; called by muse, mutect2, varscan2
- DNAH7 | c.11982G>A p.T3994= | Silent (SNP) | VAF 322/447 reads (72%) | catalogued as rs781492764, COSV56753497; called by muse, mutect2, varscan2
- DOCK3 | c.3564C>A p.S1188= | Silent (SNP) | VAF 224/475 reads (47%) | called by muse, mutect2, varscan2
- DUSP8 | c.1428C>T p.F476= | Silent (SNP) | VAF 681/794 reads (86%) | called by muse, mutect2, varscan2
- EBF1 | c.1656G>A p.V552= | Silent (SNP) | VAF 250/536 reads (47%) | called by muse, mutect2, varscan2
- EMC3 | c.42C>T p.L14= | Silent (SNP) | VAF 197/418 reads (47%) | called by muse, mutect2, varscan2
- EP300 | c.384G>A p.Q128= | Silent (SNP) | VAF 261/534 reads (49%) | catalogued as rs1244840343; called by muse, mutect2, varscan2
- EPPK1 | c.4503G>A p.V1501= | Silent (SNP) | VAF 227/1119 reads (20%) | called by muse, mutect2, varscan2
- FAM187A | c.843G>A p.L281= | Silent (SNP) | VAF 316/495 reads (64%) | catalogued as rs1316120304; called by muse, mutect2, varscan2
- FAM83D | c.1026G>A p.R342= | Silent (SNP) | VAF 187/479 reads (39%) | catalogued as rs1317399360; called by muse, mutect2, varscan2
- FBLN2 | c.2682C>T p.A894= | Silent (SNP) | VAF 175/333 reads (53%) | called by muse, mutect2, varscan2
- FBN3 | c.3750C>T p.L1250= | Silent (SNP) | VAF 165/179 reads (92%) | called by muse, mutect2, varscan2
- FCGR2C | c.522C>T p.S174= | Silent (SNP) | VAF 173/564 reads (31%) | catalogued as rs1215720190, COSV100913165; called by muse, mutect2, varscan2
- FLNC | c.6639C>T p.V2213= | Silent (SNP) | VAF 224/582 reads (38%) | catalogued as rs747628268, COSV57961194; ClinVar: likely benign; called by muse, mutect2, varscan2
- FMN2 | c.1350C>T p.S450= | Silent (SNP) | VAF 365/690 reads (53%) | catalogued as COSV60424626; called by muse, mutect2, varscan2
- FMO1 | c.885G>A p.G295= | Silent (SNP) | VAF 167/401 reads (42%) | called by muse, mutect2, varscan2
- FOXD4L5 | c.1092C>T p.I364= | Silent (SNP) | VAF 31/181 reads (17%) | called by mutect2, varscan2
- FYB2 | c.723C>T p.P241= | Silent (SNP) | VAF 208/362 reads (57%) | called by muse, mutect2, varscan2
- FZD8 | c.1593C>T p.I531= | Silent (SNP) | VAF 363/364 reads (100%) | called by muse, mutect2, varscan2
- GABRA1 | c.126C>T p.F42= | Silent (SNP) | VAF 241/462 reads (52%) | catalogued as COSV50102405; called by muse, mutect2, varscan2
- GAK | c.1951C>T p.L651= | Silent (SNP) | VAF 257/406 reads (63%) | called by muse, mutect2, varscan2
- GAPDHS | c.114C>T p.P38= | Silent (SNP) | VAF 422/446 reads (95%) | catalogued as rs770955107; called by muse, mutect2, varscan2
- GCN1 | c.2016C>T p.I672= | Silent (SNP) | VAF 260/413 reads (63%) | catalogued as COSV56104650; called by muse, mutect2, varscan2
- GLT1D1 | c.777G>A p.L259= (on ENST00000442111 / NM_001366889.1; = p.L179= on NM_144669.3) | Silent (SNP) | VAF 168/252 reads (67%) | catalogued as rs927364236; called by muse, mutect2, varscan2
- GPR139 | c.81C>T p.F27= | Silent (SNP) | VAF 250/278 reads (90%) | catalogued as COSV58501474; called by muse, mutect2, varscan2
- GPRC5B | c.141C>T p.S47= | Silent (SNP) | VAF 27/437 reads (6%) | catalogued as rs745928242; called by muse, mutect2
- GRIA2 | c.987C>T p.D329= | Silent (SNP) | VAF 110/342 reads (32%) | called by muse, varscan2
- GRID2IP | c.1488C>T p.S496= | Silent (SNP) | VAF 317/558 reads (57%) | called by muse, mutect2, varscan2
- GRM4 | c.2589C>T p.V863= | Silent (SNP) | VAF 393/709 reads (55%) | catalogued as rs1375808367; called by muse, mutect2, varscan2
- GUCY2F | c.1956G>A p.L652= | Silent (SNP) | VAF 141/141 reads (100%) | called by muse, mutect2, varscan2
- GUCY2F | c.1641C>T p.S547= | Silent (SNP) | VAF 197/197 reads (100%) | called by muse, mutect2, varscan2
- H1-2 | c.174T>A p.S58= | Silent (SNP) | VAF 22/715 reads (3%) | catalogued as COSV59190959; called by muse, mutect2
- H3C4 | c.402G>A p.E134= | Silent (SNP) | VAF 161/382 reads (42%) | called by muse, mutect2, varscan2
- HDC | c.1806C>T p.A602= | Silent (SNP) | VAF 251/399 reads (63%) | called by muse, mutect2, varscan2
- HIPK4 | c.225C>T p.F75= | Silent (SNP) | VAF 321/345 reads (93%) | called by muse, mutect2, varscan2
- HYDIN | c.9208C>T p.L3070= | Silent (SNP) | VAF 186/275 reads (68%) | called by muse, mutect2, varscan2
- ICAM1 | c.1239C>T p.S413= | Silent (SNP) | VAF 230/250 reads (92%) | catalogued as COSV99320827; called by muse, mutect2, varscan2
- IDH3B | c.873C>T p.V291= | Silent (SNP) | VAF 227/387 reads (59%) | catalogued as rs1360163081, COSV61391676; called by muse, mutect2, varscan2
- IGSF3 | c.1380C>T p.I460= (on ENST00000369486 / NM_001007237.3; = p.I480= on NM_001542.4) | Silent (SNP) | VAF 352/679 reads (52%) | called by muse, mutect2, varscan2
- IL27 | c.492G>A p.E164= | Silent (SNP) | VAF 282/312 reads (90%) | called by muse, varscan2
- INPP5E | c.96G>A p.P32= | Silent (SNP) | VAF 223/487 reads (46%) | called by muse, mutect2, varscan2
- IRAG2 | c.174A>G p.E58= | Silent (SNP) | VAF 418/704 reads (59%) | called by muse, mutect2, varscan2
- IRS2 | c.2925C>T p.L975= | Silent (SNP) | VAF 439/947 reads (46%) | called by muse, mutect2, varscan2
- ITK | c.315C>T p.A105= | Silent (SNP) | VAF 136/343 reads (40%) | catalogued as rs1360242669; called by muse, mutect2, varscan2
- ITPR1 | c.4692C>T p.L1564= (on ENST00000354582; = p.L1549= on NM_002222.7) | Silent (SNP) | VAF 220/446 reads (49%) | catalogued as rs375679048; called by muse, mutect2, varscan2
- ITPR3 | c.1689C>T p.S563= | Silent (SNP) | VAF 213/632 reads (34%) | called by muse, mutect2, varscan2
- JAK1 | c.2205C>T p.I735= | Silent (SNP) | VAF 198/509 reads (39%) | catalogued as rs751933525; called by muse, varscan2
- JPH3 | c.1185C>T p.A395= | Silent (SNP) | VAF 257/258 reads (100%) | catalogued as rs201763624; called by muse, mutect2, varscan2
- KANK2 | c.198C>T p.R66= | Silent (SNP) | VAF 344/371 reads (93%) | called by muse, mutect2, varscan2
- KCNB1 | c.1518C>T p.T506= | Silent (SNP) | VAF 286/457 reads (63%) | catalogued as rs775774087; called by muse, mutect2, varscan2
- KCNB2 | c.81T>C p.I27= | Silent (SNP) | VAF 756/899 reads (84%) | called by muse, mutect2, varscan2
- KCNC4 | c.762C>T p.D254= | Silent (SNP) | VAF 234/458 reads (51%) | called by muse, mutect2, varscan2
- KCNG1 | c.1239C>T p.A413= | Silent (SNP) | VAF 281/436 reads (64%) | called by muse, mutect2, varscan2
- KCNH6 | c.1068C>T p.F356= | Silent (SNP) | VAF 286/529 reads (54%) | catalogued as rs774234991, COSV59003343; called by muse, mutect2, varscan2
- KCP | c.762C>T p.F254= (on ENST00000620378; = p.F311= on NM_001366122.1) | Silent (SNP) | VAF 122/363 reads (34%) | called by muse, mutect2, varscan2
- KIAA1217 | c.1008C>T p.R336= | Silent (SNP) | VAF 348/350 reads (99%) | called by muse, mutect2, varscan2
- KLF6 | c.310C>T p.L104= | Silent (SNP) | VAF 250/250 reads (100%) | called by muse, mutect2, varscan2
- KMT2D | c.7653C>T p.V2551= | Silent (SNP) | VAF 538/881 reads (61%) | called by muse, mutect2, varscan2
- KRTAP10-12 | c.588C>T p.S196= | Silent (SNP) | VAF 434/866 reads (50%) | catalogued as rs372693810; called by muse, varscan2
- KYNU | c.396C>T p.A132= | Silent (SNP) | VAF 89/181 reads (49%) | called by muse, mutect2, varscan2
- LAS1L | c.993C>T p.F331= | Silent (SNP) | VAF 252/252 reads (100%) | catalogued as COSV56706931; called by muse, mutect2, varscan2
- LAYN | c.291C>T p.L97= (on ENST00000375615 / NM_001258390.1; = p.L89= on NM_178834.5) | Silent (SNP) | VAF 263/404 reads (65%) | called by muse, mutect2, varscan2
- LCK | c.357G>A p.A119= | Silent (SNP) | VAF 182/434 reads (42%) | catalogued as rs778915733, COSV60740598; called by muse, mutect2, varscan2
- LHX6 | c.294C>T p.S98= (on ENST00000373755 / NM_001242334.2; = p.S127= on NM_014368.5) | Silent (SNP) | VAF 152/333 reads (46%) | called by muse, mutect2, varscan2
- LIF | c.267C>T p.F89= | Silent (SNP) | VAF 180/353 reads (51%) | called by muse, mutect2, varscan2
- LPA | c.4671G>A p.G1557= | Silent (SNP) | VAF 265/265 reads (100%) | catalogued as COSV60300829; called by muse, mutect2, varscan2
- LRWD1 | c.1365G>A p.P455= | Silent (SNP) | VAF 299/511 reads (59%) | catalogued as rs572272292, COSV52961047, COSV52961789; called by muse, mutect2, varscan2
- LYST | c.10527G>A p.R3509= | Silent (SNP) | VAF 182/376 reads (48%) | catalogued as COSV67704054; called by muse, mutect2, varscan2
- LZIC | c.417G>A p.R139= | Silent (SNP) | VAF 156/328 reads (48%) | catalogued as rs1348206411; called by muse, mutect2, varscan2
- MAGEL2 | c.891G>A p.P297= | Silent (SNP) | VAF 366/574 reads (64%) | catalogued as rs758018158; called by muse, mutect2, varscan2
- MAP1A | c.3216C>T p.A1072= | Silent (SNP) | VAF 233/366 reads (64%) | called by muse, varscan2
- MAPK4 | c.957G>A p.E319= | Silent (SNP) | VAF 335/838 reads (40%) | called by muse, mutect2, varscan2
- MARCHF4 | c.1224G>A p.T408= | Silent (SNP) | VAF 139/197 reads (71%) | catalogued as rs201288119, COSV56104315; called by muse, mutect2, varscan2
- MARCO | c.12G>A p.K4= | Silent (SNP) | VAF 156/236 reads (66%) | catalogued as COSV59052913, COSV59055910; called by muse, mutect2, varscan2
- MGAM2 | c.4824C>T p.F1608= | Silent (SNP) | VAF 118/322 reads (37%) | called by muse, mutect2, varscan2
- MMP13 | c.555G>T p.L185= | Silent (SNP) | VAF 176/271 reads (65%) | called by muse, mutect2, varscan2
- MMP14 | c.1731C>T p.S577= | Silent (SNP) | VAF 262/387 reads (68%) | catalogued as COSV61287472; called by muse, mutect2, varscan2
- MMP28 | c.984C>T p.F328= | Silent (SNP) | VAF 239/370 reads (65%) | catalogued as rs368107958; called by muse, varscan2
- MROH2A | c.4389G>A p.G1463= | Silent (SNP) | VAF 432/606 reads (71%) | catalogued as rs774060010; called by muse, mutect2, varscan2
- MS4A4E | c.63G>A p.L21= | Silent (SNP) | VAF 185/295 reads (63%) | called by muse, mutect2, varscan2
- MTNR1A | c.348C>T p.F116= | Silent (SNP) | VAF 122/414 reads (29%) | called by muse, mutect2, varscan2
- MTRES1 | c.705G>A p.K235= | Silent (SNP) | VAF 162/163 reads (99%) | catalogued as rs782521747; called by muse, mutect2, varscan2
- MYH11 | c.2877G>A p.L959= | Silent (SNP) | VAF 20/228 reads (9%) | called by muse, mutect2
- MYH2 | c.1629C>T p.F543= | Silent (SNP) | VAF 194/194 reads (100%) | catalogued as rs761000564, COSV99819676; called by muse, mutect2, varscan2
- MYO1F | c.1215C>T p.F405= | Silent (SNP) | VAF 156/162 reads (96%) | catalogued as rs779481404, COSV57793386; called by muse, mutect2, varscan2
- NAGA | c.267C>T p.G89= | Silent (SNP) | VAF 320/762 reads (42%) | catalogued as COSV67169779; called by muse, mutect2, varscan2
- NAGK | c.78C>T p.I26= | Silent (SNP) | VAF 117/193 reads (61%) | called by muse, mutect2, varscan2
- NEB | c.6489G>A p.Q2163= | Silent (SNP) | VAF 125/196 reads (64%) | catalogued as rs747215131, COSV51431076; called by muse, mutect2, varscan2
- NEPRO | c.669T>G p.P223= | Silent (SNP) | VAF 220/220 reads (100%) | called by muse, mutect2, varscan2
- NLRP3 | c.855C>T p.I285= | Silent (SNP) | VAF 195/437 reads (45%) | called by muse, mutect2, varscan2
- NLRP7 | c.2862G>A p.V954= (on ENST00000340844 / NM_206828.3; = p.V983= on NM_139176.3) | Silent (SNP) | VAF 19/334 reads (6%) | called by muse, mutect2
- NPM3 | c.114C>T p.F38= | Silent (SNP) | VAF 212/215 reads (99%) | catalogued as COSV63380874; called by mutect2, varscan2
- OBSCN | c.15288G>A p.R5096= | Silent (SNP) | VAF 202/489 reads (41%) | called by muse, varscan2
- OCM | c.255C>T p.S85= | Silent (SNP) | VAF 97/282 reads (34%) | catalogued as rs779549074; called by muse, mutect2, varscan2
- OLFML2B | c.1758C>T p.I586= | Silent (SNP) | VAF 199/464 reads (43%) | catalogued as COSV99668368; called by muse, mutect2, varscan2
- OR10G2 | c.48C>T p.F16= | Silent (SNP) | VAF 147/434 reads (34%) | catalogued as COSV73390299; called by muse, mutect2, varscan2
- OR10H4 | c.651C>T p.I217= | Silent (SNP) | VAF 284/305 reads (93%) | catalogued as rs1436466816, COSV59061224; called by muse, mutect2, varscan2
- OR11H2 | c.925C>T p.L309= (on ENST00000556246; = p.L320= on NM_001197287.1) | Silent (SNP) | VAF 46/321 reads (14%) | called by muse, mutect2, varscan2
- OR2V1 | c.552T>C p.A184= | Silent (SNP) | VAF 216/458 reads (47%) | called by muse, mutect2, varscan2
- OR4C15 | c.810C>T p.S270= (on ENST00000314644; = p.S216= on NM_001001920.2) | Silent (SNP) | VAF 118/361 reads (33%) | catalogued as COSV58953246; called by muse, mutect2, varscan2
- OR4K2 | c.855A>T p.I285= | Silent (SNP) | VAF 111/371 reads (30%) | catalogued as COSV100064686; called by muse, mutect2, varscan2
- OR51L1 | c.939G>A p.R313= | Silent (SNP) | VAF 132/208 reads (63%) | catalogued as rs1437749839; called by muse, mutect2, varscan2
- OR52B2 | c.27C>T p.F9= | Silent (SNP) | VAF 99/156 reads (63%) | catalogued as rs1280857659; called by muse, varscan2
- OR5T3 | c.696C>T p.F232= | Silent (SNP) | VAF 263/422 reads (62%) | catalogued as COSV100282735, COSV100282964; called by muse, mutect2, varscan2
- OR6N1 | c.153G>A p.L51= | Silent (SNP) | VAF 446/714 reads (62%) | called by muse, mutect2, varscan2
- OSM | c.252G>A p.E84= | Silent (SNP) | VAF 218/419 reads (52%) | called by muse, mutect2, varscan2
- P2RX1 | c.1170G>A p.L390= | Silent (SNP) | VAF 288/288 reads (100%) | catalogued as rs1275545954, COSV99340078; called by muse, mutect2, varscan2
- PAPLN | c.2869C>T p.L957= (on ENST00000554301; = p.L930= on NM_173462.4) | Silent (SNP) | VAF 130/220 reads (59%) | called by muse, mutect2, varscan2
- PBX4 | c.969C>T p.F323= | Silent (SNP) | VAF 222/234 reads (95%) | called by muse, mutect2, varscan2
- PCDHA11 | c.2286C>T p.G762= | Silent (SNP) | VAF 299/623 reads (48%) | called by muse, mutect2, varscan2
- PCDHA13 | c.1785C>T p.R595= | Silent (SNP) | VAF 20/694 reads (3%) | catalogued as rs782043806, COSV56521650; called by muse, mutect2
- PCSK5 | c.2568C>T p.C856= | Silent (SNP) | VAF 94/201 reads (47%) | catalogued as rs138803714; called by muse, mutect2, varscan2
- PDE6A | c.1680C>T p.N560= | Silent (SNP) | VAF 233/426 reads (55%) | called by muse, mutect2, varscan2
- PLA2G3 | c.39C>T p.F13= | Silent (SNP) | VAF 133/306 reads (43%) | called by muse, mutect2, varscan2
- PLIN1 | c.1356C>T p.P452= | Silent (SNP) | VAF 216/580 reads (37%) | called by muse, mutect2, varscan2
- PLS3 | c.903C>T p.A301= | Silent (SNP) | VAF 152/152 reads (100%) | called by muse, mutect2, varscan2
- PLXNA1 | c.1452C>T p.S484= | Silent (SNP) | VAF 340/340 reads (100%) | called by muse, mutect2, varscan2
- POTEC | c.1104C>T p.I368= | Silent (SNP) | VAF 22/104 reads (21%) | catalogued as rs267605121; called by muse, mutect2, varscan2
- PPIL1 | c.474G>A p.K158= | Silent (SNP) | VAF 204/496 reads (41%) | catalogued as COSV65473085; called by muse, mutect2, varscan2
- PRG4 | c.2193G>A p.K731= | Silent (SNP) | VAF 345/789 reads (44%) | catalogued as COSV63355115; called by muse, mutect2, varscan2
- PRPF40B | c.1695C>T p.I565= (on ENST00000380281; = p.I559= on NM_012272.3) | Silent (SNP) | VAF 238/433 reads (55%) | catalogued as rs150651073; called by muse, mutect2, varscan2
- PSMG3 | c.162C>T p.A54= | Silent (SNP) | VAF 192/192 reads (100%) | called by muse, mutect2, varscan2
- R3HCC1 | c.1278C>T p.T426= (on ENST00000411463; = p.T386= on NM_001136108.3) | Silent (SNP) | VAF 174/175 reads (99%) | called by muse, varscan2
- RAD21L1 | c.897C>T p.L299= | Silent (SNP) | VAF 87/266 reads (33%) | called by muse, mutect2, varscan2
- RALGDS | c.1941C>T p.P647= | Silent (SNP) | VAF 143/274 reads (52%) | catalogued as COSV64429716; called by muse, mutect2, varscan2
- REG1A | c.24C>T p.F8= | Silent (SNP) | VAF 134/397 reads (34%) | catalogued as COSV52068337, COSV52068377; called by muse, mutect2, varscan2
- RGPD3 | c.1503G>A p.K501= | Silent (SNP) | VAF 81/408 reads (20%) | called by muse, mutect2, varscan2
- RHBDF1 | c.423C>T p.P141= | Silent (SNP) | VAF 280/606 reads (46%) | catalogued as COSV99244977; called by muse, mutect2, varscan2
- RICTOR | c.78C>T p.V26= | Silent (SNP) | VAF 234/485 reads (48%) | called by muse, varscan2
- RIMS2 | c.4029G>A p.R1343= | Silent (SNP) | VAF 95/700 reads (14%) | called by muse, mutect2, varscan2
- RINL | c.297C>T p.I99= | Silent (SNP) | VAF 206/226 reads (91%) | called by muse, mutect2, varscan2
- SCRT2 | c.390G>A p.G130= | Silent (SNP) | VAF 55/112 reads (49%) | catalogued as rs1568651391; called by muse, mutect2, varscan2
- SEPTIN4 | c.310C>T p.L104= | Silent (SNP) | VAF 240/369 reads (65%) | called by muse, mutect2, varscan2
- SERPINA7 | c.1182G>A p.L394= | Silent (SNP) | VAF 253/253 reads (100%) | catalogued as COSV59665521; called by muse, mutect2, varscan2
- SLC13A3 | c.1143C>T p.T381= | Silent (SNP) | VAF 158/259 reads (61%) | catalogued as rs140812730; called by muse, mutect2, varscan2
- SLC30A8 | c.1101C>T p.P367= | Silent (SNP) | VAF 87/448 reads (19%) | catalogued as rs1287611379, COSV69969708; called by muse, mutect2, varscan2
- SLC8A3 | c.2382C>T p.F794= (on ENST00000381269 / NM_183002.3; = p.F792= on NM_033262.4) | Silent (SNP) | VAF 229/364 reads (63%) | catalogued as rs368263429; called by muse, mutect2, varscan2
- SLC9C2 | c.2847G>A p.E949= | Silent (SNP) | VAF 213/393 reads (54%) | called by muse, mutect2, varscan2
- SLITRK6 | c.1167G>A p.L389= | Silent (SNP) | VAF 157/312 reads (50%) | called by muse, mutect2, varscan2
- SMG5 | c.2184C>T p.L728= | Silent (SNP) | VAF 437/688 reads (64%) | called by muse, mutect2, varscan2
- SMIM23 | c.363G>A p.L121= | Silent (SNP) | VAF 235/430 reads (55%) | called by muse, mutect2, varscan2
- SNTG2 | c.228C>T p.L76= | Silent (SNP) | VAF 230/382 reads (60%) | catalogued as COSV57986069; called by muse, mutect2
- SOAT1 | c.663C>A p.L221= | Silent (SNP) | VAF 219/467 reads (47%) | catalogued as COSV62654083, COSV62656873; called by muse, mutect2, varscan2
- SPATA5L1 | c.639G>A p.R213= | Silent (SNP) | VAF 375/583 reads (64%) | called by muse, mutect2, varscan2
- SSC4D | c.1608C>T p.L536= | Silent (SNP) | VAF 348/570 reads (61%) | catalogued as COSV99300082; called by muse, mutect2, varscan2
- STAT3 | c.1995C>T p.I665= | Silent (SNP) | VAF 244/382 reads (64%) | catalogued as COSV52888488; called by muse, mutect2, varscan2
- STIL | c.897C>T p.F299= | Silent (SNP) | VAF 93/204 reads (46%) | called by muse, mutect2, varscan2
- TACC2 | c.1326G>A p.R442= | Silent (SNP) | VAF 311/313 reads (99%) | called by muse, mutect2, varscan2
- TAF3 | c.945C>T p.S315= | Silent (SNP) | VAF 310/312 reads (99%) | called by muse, mutect2, varscan2
- TANC2 | c.3375C>T p.S1125= | Silent (SNP) | VAF 149/284 reads (52%) | called by muse, mutect2, varscan2
- TATDN2 | c.1953G>A p.K651= | Silent (SNP) | VAF 105/213 reads (49%) | called by muse, mutect2, varscan2
- TFEB | c.996C>T p.S332= | Silent (SNP) | VAF 535/878 reads (61%) | called by muse, mutect2, varscan2
- THRB | c.1206C>T p.A402= | Silent (SNP) | VAF 229/467 reads (49%) | called by muse, mutect2, varscan2
- THSD1 | c.2412C>T p.P804= | Silent (SNP) | VAF 161/357 reads (45%) | catalogued as rs776907289; called by muse, mutect2, varscan2
- TJP3 | c.885G>A p.S295= | Silent (SNP) | VAF 290/308 reads (94%) | catalogued as rs553055182; called by muse, mutect2, varscan2
- TMEM132B | c.1317G>A p.K439= | Silent (SNP) | VAF 227/331 reads (69%) | catalogued as COSV54765855; called by muse, mutect2, varscan2
- TMEM14B | c.264C>T p.F88= | Silent (SNP) | VAF 206/552 reads (37%) | catalogued as COSV101077475; called by muse, mutect2, varscan2
- TMEM176A | c.462C>T p.S154= | Silent (SNP) | VAF 222/380 reads (58%) | called by muse, mutect2, varscan2
- TMEM8B | c.54C>T p.S18= | Silent (SNP) | VAF 265/492 reads (54%) | catalogued as rs762579513, COSV65077986; called by muse, mutect2, varscan2
- TMPRSS13 | c.1188C>T p.S396= | Silent (SNP) | VAF 152/446 reads (34%) | called by muse, varscan2
- TRAV26-1 | c.132C>T p.I44= | Silent (SNP) | VAF 113/366 reads (31%) | called by muse, mutect2
- VPS13B | c.6351G>A p.K2117= | Silent (SNP) | VAF 638/773 reads (83%) | called by muse, mutect2, varscan2
- VPS13C | c.7836G>A p.K2612= (on ENST00000644861 / NM_020821.3; = p.K2569= on NM_017684.5) | Silent (SNP) | VAF 100/335 reads (30%) | called by muse, varscan2
- WDR70 | c.1176C>T p.V392= | Silent (SNP) | VAF 169/334 reads (51%) | catalogued as rs1326288676; called by muse, mutect2, varscan2
- XCR1 | c.282C>T p.G94= | Silent (SNP) | VAF 225/449 reads (50%) | called by muse, mutect2, varscan2
- YIPF6 | c.138C>T p.I46= | Silent (SNP) | VAF 223/224 reads (100%) | catalogued as COSV65856224; called by muse, mutect2, varscan2
- ZBTB46 | c.1095C>T p.T365= | Silent (SNP) | VAF 223/594 reads (38%) | catalogued as rs759299672, COSV55513971; called by muse, mutect2, varscan2
- ZFAT | c.2340C>A p.I780= | Silent (SNP) | VAF 388/686 reads (57%) | called by muse, mutect2, varscan2
- ZFP57 | c.1113C>T p.S371= | Silent (SNP) | VAF 203/1036 reads (20%) | called by muse, mutect2, varscan2
- ZFPM2 | c.1350G>A p.T450= | Silent (SNP) | VAF 854/996 reads (86%) | catalogued as rs951468447, COSV65874594; called by muse, mutect2, varscan2
- ZNF688 | c.72G>T p.G24= | Silent (SNP) | VAF 385/815 reads (47%) | called by muse, mutect2, varscan2
- ABCD1 | c.1081+22G>A | Intron (SNP) | VAF 411/411 reads (100%) | called by muse, mutect2, varscan2
- ADRA2B | c.*1598G>A | 3'UTR (SNP) | VAF 92/388 reads (24%) | called by muse, mutect2, varscan2
- ATAD3B | c.*286G>A | 3'UTR (SNP) | VAF 148/273 reads (54%) | called by muse, mutect2, varscan2
- CD6 | c.*875C>T | 3'UTR (SNP) | VAF 252/387 reads (65%) | called by muse, mutect2, varscan2
- DNAH14 | c.5584+5656C>T | Intron (SNP) | VAF 138/299 reads (46%) | called by muse, mutect2, varscan2
- GNAS | chr20:58850555 C>T | 5'Flank (SNP) | VAF 146/256 reads (57%) | called by muse, mutect2, varscan2
- H2BP2 | n.1061+620C>T | Intron (SNP) | VAF 95/372 reads (26%) | catalogued as rs1442834717; called by muse, varscan2
- ISCA2P1 | chr22:26646829 G>A | 5'Flank (SNP) | VAF 146/290 reads (50%) | called by muse, varscan2
- JAKMIP1 | chr4:6049827 C>T | 3'Flank (SNP) | VAF 100/254 reads (39%) | catalogued as rs1274174883, COSV51524978; called by muse, mutect2, varscan2
- KCNH7 | c.2154+18C>T | Intron (SNP) | VAF 112/390 reads (29%) | called by muse, mutect2, varscan2
- KCNQ1 | c.1393+22041C>T | Intron (SNP) | VAF 82/461 reads (18%) | catalogued as rs1159913886; called by muse, mutect2, varscan2
- KLHL9 | c.-431G>A | 5'UTR (SNP) | VAF 155/292 reads (53%) | called by muse, mutect2, varscan2
- MGAM | c.4619-12132C>T | Intron (SNP) | VAF 87/263 reads (33%) | catalogued as rs1374095421; called by muse, mutect2, varscan2
- MLIP | c.613-11063C>T | Intron (SNP) | VAF 147/503 reads (29%) | called by muse, mutect2, varscan2
- OR10J1 | c.-19C>T | 5'UTR (SNP) | VAF 128/392 reads (33%) | catalogued as COSV71129676; called by muse, mutect2, varscan2
- OR2T8 | chr1:247921017 C>T | 5'Flank (SNP) | VAF 112/270 reads (41%) | catalogued as COSV100178398; called by muse, mutect2, varscan2
- PRRG3 | c.168+9C>T | Intron (SNP) | VAF 325/325 reads (100%) | called by muse, mutect2, varscan2
- SCNN1B | c.-9+21120G>A | Intron (SNP) | VAF 18/230 reads (8%) | called by muse, mutect2
- TMC5 | c.1049-3496C>T | Intron (SNP) | VAF 150/169 reads (89%) | catalogued as COSV54903009; called by muse, mutect2, varscan2
- TMEM99 | n.541C>T | RNA (SNP) | VAF 266/400 reads (67%) | called by muse, mutect2
- TTN | c.10361-4254C>T | Intron (SNP) | VAF 267/373 reads (72%) | called by muse, mutect2, varscan2
- VIPR2 | c.357+6685C>T | Intron (SNP) | VAF 348/596 reads (58%) | called by muse, mutect2, varscan2
- ZNF451 | c.186+2285C>T | Intron (SNP) | VAF 304/465 reads (65%) | called by muse, mutect2, varscan2
